Somatic mutation profile of tumor specimen C3N-01871-01 (aliquot CPT0117010007) from CPTAC case C3N-01871, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G2; Age at diagnosis: 77.7 years (28,366 days).
Specimen C3N-01871-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) deea57ad-8605-4dde-968c-e89c02115397.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01871-31 (Blood Derived Normal), aliquot CPT0117110002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/865b860c-642c-4718-badf-d857427e4ba4

The open-access MAF lists 933 somatic variants for this specimen: 596 protein-altering or splice-affecting, 199 silent, 138 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 425, Silent 199, Frame Shift Del 96, Intron 78, Nonsense Mutation 30, Frame Shift Ins 20, RNA 19, 3'UTR 19, 5'UTR 13, Splice Site 12, 5'Flank 8, Splice Region 7.

Variants (750 of 933; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALDH7A1 | c.1003C>T p.R335* | Nonsense Mutation (SNP) | VAF 117/819 reads (14%) | catalogued as rs1015686016, CM070012, COSV69259234; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ERBB2 | c.2264T>C p.L755S | Missense Mutation (SNP) | VAF 22/210 reads (10%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913470, COSV54062780, COSV54064269; ClinVar: likely pathogenic; called by muse, varscan2
- KANSL1 | c.2899del p.Q967Sfs*46 (on ENST00000574590 / NM_001193465.2; = p.Q968Sfs*46 on NM_015443.4) | Frame Shift Del (DEL) | VAF 9/49 reads (18%) | catalogued as rs1374665357; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 85/337 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- MAX | c.179G>A p.R60Q | Missense Mutation (SNP) | VAF 174/694 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52414939; called by muse, mutect2, varscan2
- NBN | c.1396del p.R466Gfs*18 | Frame Shift Del (DEL) | VAF 47/188 reads (25%) | catalogued as rs1349928568; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- NDE1 | c.733del p.L245Sfs*26 (on ENST00000577101; = p.L245Sfs*113 on NM_017668.3) | Frame Shift Del (DEL) | VAF 81/822 reads (10%) | catalogued as rs749768828; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- NKX6-2 | c.234del p.L79Cfs*109 | Frame Shift Del (DEL) | VAF 20/95 reads (21%) | catalogued as rs765650727; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- OFD1 | c.710del p.K237Sfs*6 | Frame Shift Del (DEL) | VAF 16/92 reads (17%) | catalogued as rs312262845; ClinVar: pathogenic; called by mutect2, varscan2
- PIK3R1 | c.1728_1730del p.R577del (on ENST00000521381 / NM_181523.3; = p.R307del on NM_181504.4) | In Frame Del (DEL) | VAF 26/116 reads (22%) | hotspot (GDC flag); catalogued as COSV57133583; called by mutect2, pindel, varscan2
- PTEN | c.987_990del p.N329Kfs*14 | Frame Shift Del (DEL) | VAF 138/233 reads (59%) | catalogued as rs587782304; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- SGCD | c.490C>T p.R164* (on ENST00000435422 / NM_001128209.2; = p.R165* on NM_000337.5) | Nonsense Mutation (SNP) | VAF 16/120 reads (13%) | catalogued as rs121909295, CM971352; ClinVar: pathogenic; called by muse, mutect2
- ABHD14A-ACY1 | c.329C>T p.S110L | Missense Mutation (SNP) | VAF 24/410 reads (6%) | SIFT deleterious, low confidence (0); catalogued as rs748035101; called by muse, mutect2
- AC011005.1 | c.637G>A p.G213R | Missense Mutation (SNP) | VAF 229/755 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs557539124; called by muse, mutect2, varscan2
- ACTC1 | c.527C>T p.A176V | Missense Mutation (SNP) | VAF 30/648 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.036); catalogued as COSV99291606; called by muse, mutect2
- ADAMTSL4 | c.1919G>A p.G640D | Missense Mutation (SNP) | VAF 16/526 reads (3%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.976); catalogued as COSV55003835; called by muse, mutect2
- ADCK5 | c.1465G>A p.A489T | Missense Mutation (SNP) | VAF 166/609 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.435); catalogued as rs1554861425, COSV58235722; called by muse, mutect2, varscan2
- ADCY6 | c.3467A>G p.E1156G | Missense Mutation (SNP) | VAF 62/264 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.811); catalogued as COSV57168519; called by muse, mutect2, varscan2
- ADCYAP1R1 | c.569T>C p.M190T | Missense Mutation (SNP) | VAF 26/215 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs748774130; called by muse, mutect2, varscan2
- ADRA2A | c.342G>A p.W114* | Nonsense Mutation (SNP) | VAF 138/723 reads (19%) | catalogued as rs1301045683; called by muse, mutect2, varscan2
- AFDN | c.250C>T p.R84* | Nonsense Mutation (SNP) | VAF 29/241 reads (12%) | catalogued as COSV60036499; called by muse, mutect2, varscan2
- AMPH | c.859G>A p.A287T | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.91); catalogued as rs368302578; called by muse, mutect2, varscan2
- ANK2 | c.6874C>T p.R2292* | Nonsense Mutation (SNP) | VAF 32/181 reads (18%) | catalogued as COSV100001468; called by muse, mutect2, varscan2
- ANKRD28 | c.2249C>T p.A750V | Missense Mutation (SNP) | VAF 183/627 reads (29%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs1251150317; called by muse, mutect2, varscan2
- ANKRD36C | c.2401T>G p.F801V | Missense Mutation (SNP) | VAF 42/400 reads (11%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.006); catalogued as COSV54765169; called by muse, mutect2, varscan2
- ANO7 | c.2597G>A p.R866H (on ENST00000274979; = p.R812H on NM_001370694.2) | Missense Mutation (SNP) | VAF 124/501 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.212); catalogued as rs747882691; called by muse, mutect2, varscan2
- ANTKMT | c.260G>A p.G87D | Missense Mutation (SNP) | VAF 134/492 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1391757453; called by muse, mutect2, varscan2
- APBA1 | c.1280C>T p.A427V | Missense Mutation (SNP) | VAF 33/322 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.017); catalogued as rs760771546, COSV55226831; called by muse, mutect2, varscan2
- APBA1 | c.326C>T p.A109V | Missense Mutation (SNP) | VAF 13/366 reads (4%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); catalogued as rs1012439301, COSV55236683; called by muse, mutect2
- ARID1A | c.2296del p.Q766Sfs*67 | Frame Shift Del (DEL) | VAF 26/205 reads (13%) | catalogued as COSV61372766; called by mutect2, pindel, varscan2
- ARSJ | c.1736del p.K579Rfs*30 | Frame Shift Del (DEL) | VAF 28/228 reads (12%) | catalogued as rs753865255; called by mutect2, varscan2
- ASB18 | c.586G>A p.A196T | Missense Mutation (SNP) | VAF 128/531 reads (24%) | SIFT tolerated (0.51); PolyPhen benign (0.36); catalogued as rs757979546; called by muse, mutect2, varscan2
- ASIC5 | c.437C>T p.A146V | Missense Mutation (SNP) | VAF 34/333 reads (10%) | SIFT tolerated (0.34); PolyPhen benign (0.044); catalogued as COSV72232693; called by muse, mutect2, varscan2
- ASS1 | c.730del p.H244Tfs*11 | Frame Shift Del (DEL) | VAF 141/1313 reads (11%) | catalogued as COSV100752869; called by mutect2, pindel, varscan2
- ATAD3A | c.1828G>A p.V610I | Missense Mutation (SNP) | VAF 36/724 reads (5%) | SIFT tolerated (0.47); PolyPhen benign (0.007); catalogued as rs1309685084; called by muse, mutect2
- ATG2B | c.4277C>T p.T1426I | Missense Mutation (SNP) | VAF 17/132 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.006); catalogued as COSV55891918; called by muse, mutect2, varscan2
- ATG9B | c.293del p.P98Qfs*8 | Frame Shift Del (DEL) | VAF 11/82 reads (13%) | catalogued as rs770350293; called by mutect2, pindel, varscan2
- ATP11B | c.2650del p.Y884Ifs*30 | Frame Shift Del (DEL) | VAF 6/41 reads (15%) | catalogued as rs759638000; called by mutect2, varscan2
- ATP2B4 | c.909dup p.Q304Tfs*5 | Frame Shift Ins (INS) | VAF 27/167 reads (16%) | catalogued as rs1250779722; called by mutect2, pindel, varscan2
- ATP6V1G3 | c.38A>G p.Q13R | Missense Mutation (SNP) | VAF 130/602 reads (22%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as rs779954548; called by muse, mutect2, varscan2
- ATP9A | c.1882C>T p.R628C | Missense Mutation (SNP) | VAF 39/285 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs547685626; called by muse, mutect2, varscan2
- B3GNT6 | c.1010C>T p.P337L | Missense Mutation (SNP) | VAF 32/704 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs781984195, COSV62827854; called by muse, mutect2
- B4GALNT4 | c.918del p.R307Vfs*100 | Frame Shift Del (DEL) | VAF 55/229 reads (24%) | catalogued as rs770737105, COSV57327371; called by mutect2, pindel, varscan2
- BACH2 | c.2267C>T p.A756V | Missense Mutation (SNP) | VAF 65/724 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs761363627, COSV57589488, COSV57596047; called by muse, mutect2
- BAHCC1 | c.7718C>T p.A2573V | Missense Mutation (SNP) | VAF 22/688 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.377); catalogued as rs781918039, COSV57025971; called by muse, mutect2
- BARX2 | c.272C>T p.P91L | Missense Mutation (SNP) | VAF 44/340 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.026); catalogued as rs143991757; called by muse, varscan2
- BAX | c.265del p.R89Efs*44 | Frame Shift Del (DEL) | VAF 8/66 reads (12%) | catalogued as COSV53170202; called by mutect2, pindel, varscan2
- BAZ1A | c.3448C>T p.R1150C | Missense Mutation (SNP) | VAF 124/463 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057335359; called by muse, mutect2, varscan2
- BEGAIN | c.1043G>A p.R348H | Missense Mutation (SNP) | VAF 48/548 reads (9%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.942); catalogued as COSV100766925; called by muse, mutect2
- BRPF3 | c.2305C>T p.R769C | Missense Mutation (SNP) | VAF 161/1375 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs748134043, COSV100326017; called by muse, mutect2, varscan2
- C16orf54 | c.538G>A p.V180I | Missense Mutation (SNP) | VAF 239/861 reads (28%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as rs199652256, COSV61476594; called by muse, mutect2, varscan2
- CACNA1E | c.7C>T p.R3C | Missense Mutation (SNP) | VAF 46/286 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs769614151, COSV62412445; called by mutect2, varscan2
- CAPN15 | c.988C>T p.R330C | Missense Mutation (SNP) | VAF 41/375 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs770511000; called by muse, mutect2, varscan2
- CAPNS1 | c.251G>A p.R84H | Missense Mutation (SNP) | VAF 75/275 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.052); catalogued as rs866083785; called by muse, mutect2, varscan2
- CATSPERD | c.302C>T p.A101V | Missense Mutation (SNP) | VAF 24/286 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs1355730634; called by muse, mutect2
- CBFA2T3 | c.1958G>A p.R653H | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as rs1461949410, COSV51924355; called by muse, mutect2
- CCDC116 | c.803G>A p.R268H | Missense Mutation (SNP) | VAF 70/669 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs147529801; called by muse, mutect2, varscan2
- CCDC74B | c.1051G>A p.A351T | Missense Mutation (SNP) | VAF 49/453 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.286); catalogued as rs140718616; called by muse, mutect2, varscan2
- CCNT2 | c.1733C>T p.S578L | Missense Mutation (SNP) | VAF 72/604 reads (12%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs749781251; called by muse, mutect2, varscan2
- CD14 | c.49G>A p.V17I | Missense Mutation (SNP) | VAF 98/373 reads (26%) | SIFT tolerated (0.28); PolyPhen benign (0.06); catalogued as COSV100117681; called by muse, mutect2, varscan2
- CDH24 | c.2135del p.P712Rfs*129 | Frame Shift Del (DEL) | VAF 94/612 reads (15%) | catalogued as rs752398646; called by mutect2, varscan2
- CDK5RAP3 | c.754C>T p.R252* | Nonsense Mutation (SNP) | VAF 41/476 reads (9%) | catalogued as rs772953445, COSV58115833; called by muse, mutect2
- CEP192 | c.2288G>A p.R763H | Missense Mutation (SNP) | VAF 40/188 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.028); catalogued as rs1003573664; called by muse, mutect2, varscan2
- CLEC12A | c.602G>A p.R201H | Missense Mutation (SNP) | VAF 52/231 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs753409256, COSV100429646; called by muse, mutect2, varscan2
- CLEC14A | c.970G>A p.D324N | Missense Mutation (SNP) | VAF 13/131 reads (10%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0.018); catalogued as rs148708409; called by muse, mutect2, varscan2
- CLSTN3 | c.2858del p.P953Hfs*106 | Frame Shift Del (DEL) | VAF 8/76 reads (11%) | catalogued as rs758841384; called by mutect2, pindel
- CNGA3 | c.397G>A p.A133T | Missense Mutation (SNP) | VAF 165/595 reads (28%) | SIFT tolerated (0.44); PolyPhen benign (0.017); catalogued as rs769185929, COSV55626188; called by muse, mutect2, varscan2
- CNTN6 | c.1253dup p.S419Vfs*33 | Frame Shift Ins (INS) | VAF 19/94 reads (20%) | catalogued as rs758676375; called by mutect2, varscan2
- CNTNAP2 | c.2657C>T p.T886I | Missense Mutation (SNP) | VAF 171/728 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.216); catalogued as rs1159658259; called by muse, mutect2, varscan2
- COL6A6 | c.5452G>A p.A1818T | Missense Mutation (SNP) | VAF 31/268 reads (12%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs781756871, COSV62019244; called by muse, mutect2, varscan2
- COL7A1 | c.7420C>T p.R2474C | Missense Mutation (SNP) | VAF 199/757 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.29); catalogued as rs939213328, COSV100097504; called by muse, mutect2, varscan2
- COPB1 | c.440G>A p.R147Q | Missense Mutation (SNP) | VAF 22/146 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs145180828; called by muse, mutect2, varscan2
- CPM | c.4G>A p.D2N | Missense Mutation (SNP) | VAF 8/166 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.841); catalogued as COSV100615119; called by muse, mutect2
- CPNE6 | c.1522C>T p.R508* | Nonsense Mutation (SNP) | VAF 105/534 reads (20%) | catalogued as COSV53745937; called by muse, mutect2, varscan2
- CRLF2 | c.7C>T p.R3W | Missense Mutation (SNP) | VAF 47/444 reads (11%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.363); catalogued as rs374874204, COSV67494236; called by muse, mutect2, varscan2
- CTBP1 | c.490G>A p.E164K | Missense Mutation (SNP) | VAF 35/996 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs868779152, COSV99337959; called by muse, mutect2
- CUL7 | c.442G>A p.A148T | Missense Mutation (SNP) | VAF 76/638 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54815778; called by muse, mutect2, varscan2
- CYP2C18 | c.1297C>T p.R433W | Missense Mutation (SNP) | VAF 46/291 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as rs753408877, COSV53675272; called by muse, mutect2, varscan2
- CYP4A11 | c.1336G>A p.A446T | Missense Mutation (SNP) | VAF 46/396 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs556756716, COSV60224205; called by muse, mutect2, varscan2
- DCHS1 | c.335G>T p.R112L | Missense Mutation (SNP) | VAF 190/671 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100202441; called by muse, mutect2, varscan2
- DCHS2 | c.1274G>A p.R425H | Missense Mutation (SNP) | VAF 31/253 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.216); catalogued as rs201027235; called by muse, mutect2, varscan2
- DDX41 | c.*439-4G>A | Splice Region (SNP) | VAF 36/149 reads (24%) | catalogued as COSV57251488; called by muse, mutect2, varscan2
- DLGAP3 | c.254dup p.S86* | Frame Shift Ins (INS) | VAF 66/282 reads (23%) | catalogued as rs762874947; called by mutect2, varscan2
- DLL1 | c.845dup p.L283Pfs*14 | Frame Shift Ins (INS) | VAF 203/845 reads (24%) | catalogued as rs760008381; called by mutect2, varscan2
- DMRT2 | c.25G>A p.A9T | Missense Mutation (SNP) | VAF 76/649 reads (12%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.043); catalogued as rs370378831; called by muse, mutect2, varscan2
- DNAH14 | c.7675dup p.I2559Nfs*2 (on ENST00000445597; = p.I3331Nfs*2 on NM_001367479.1) | Frame Shift Ins (INS) | VAF 78/396 reads (20%) | catalogued as rs765587752; called by mutect2, varscan2
- DNAH6 | c.911del p.N304Ifs*16 | Frame Shift Del (DEL) | VAF 8/75 reads (11%) | catalogued as rs763637561; called by mutect2, pindel, varscan2
- DNAH9 | c.6521G>A p.R2174H | Missense Mutation (SNP) | VAF 92/695 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs752731038, COSV52358855; called by muse, mutect2, varscan2
- DPYS | c.35del p.G12Vfs*86 | Frame Shift Del (DEL) | VAF 38/306 reads (12%) | catalogued as rs1212167138; called by mutect2, pindel
- DPYSL3 | c.1545del p.A516Qfs*15 | Frame Shift Del (DEL) | VAF 132/542 reads (24%) | catalogued as COSV58330771; called by mutect2, pindel, varscan2
- DSCAM | c.2458C>T p.R820C | Missense Mutation (SNP) | VAF 85/308 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs770386573, COSV68024473; called by muse, mutect2, varscan2
- DUSP22 | c.515C>T p.P172L | Missense Mutation (SNP) | VAF 28/623 reads (4%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.027); catalogued as rs778507659; called by muse, mutect2
- E2F1 | c.493C>T p.R165W | Missense Mutation (SNP) | VAF 242/920 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58535777; called by muse, mutect2, varscan2
- EDNRB | c.1147del p.Y383Ifs*3 (on ENST00000377211 / NM_001201397.1; = p.Y293Ifs*3 on NM_000115.5) | Frame Shift Del (DEL) | VAF 67/282 reads (24%) | catalogued as rs769735757; ClinVar: risk factor; called by mutect2, pindel, varscan2
- EEF1AKMT4-ECE2 | c.2323C>T p.R775C | Missense Mutation (SNP) | VAF 18/147 reads (12%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.817); catalogued as rs373938914, COSV62566973; called by muse, mutect2, varscan2
- EFCAB6 | c.2513A>G p.H838R | Missense Mutation (SNP) | VAF 15/341 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1473445623; called by muse, mutect2
- EHBP1L1 | c.3829G>A p.V1277M | Missense Mutation (SNP) | VAF 362/1268 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.736); catalogued as rs1162597937; called by muse, mutect2, varscan2
- EPN2 | c.1408del p.T470Qfs*5 | Frame Shift Del (DEL) | VAF 27/95 reads (28%) | catalogued as rs756461692; called by mutect2, varscan2
- ERICH6B | c.1738G>A p.A580T | Missense Mutation (SNP) | VAF 40/422 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.636); catalogued as rs112232111, COSV53918891; called by muse, mutect2
- EVPLL | c.529C>T p.R177W | Missense Mutation (SNP) | VAF 70/249 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.345); catalogued as rs1195779396, COSV101213008; called by muse, mutect2, varscan2
- F11R | c.131A>C p.N44T | Missense Mutation (SNP) | VAF 14/276 reads (5%) | SIFT tolerated (0.15); PolyPhen benign (0.116); catalogued as COSV57036471; called by muse, mutect2
- FAM76A | c.563A>G p.K188R | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.893); catalogued as COSV50548877; called by muse, mutect2, varscan2
- FAM98A | c.1390C>T p.R464* | Nonsense Mutation (SNP) | VAF 104/403 reads (26%) | catalogued as rs1396397106, COSV99478974; called by muse, mutect2, varscan2
- FAT4 | c.365G>A p.R122Q | Missense Mutation (SNP) | VAF 139/515 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as rs751046172, COSV101271808; called by muse, mutect2, varscan2
- FCHSD2 | c.1001G>A p.R334H | Missense Mutation (SNP) | VAF 27/243 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); catalogued as rs1008373651; called by muse, mutect2, varscan2
- FGB | c.957A>G p.P319= | Splice Region (SNP) | VAF 40/454 reads (9%) | catalogued as rs1166701895; called by muse, mutect2
- FGD3 | c.800G>A p.R267H | Missense Mutation (SNP) | VAF 27/234 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs758500993, COSV104399207; called by muse, mutect2
- FOXD2 | c.1048G>A p.A350T | Missense Mutation (SNP) | VAF 46/588 reads (8%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.138); catalogued as rs1272143938; called by muse, mutect2
- FREM3 | c.4690G>C p.D1564H | Missense Mutation (SNP) | VAF 33/281 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61682195; called by muse, mutect2, varscan2
- FRY | c.2051C>T p.S684L | Missense Mutation (SNP) | VAF 70/251 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.212); catalogued as rs756972894, COSV100969787; called by muse, varscan2
- GAL3ST3 | c.925G>A p.V309M | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.811); catalogued as rs1484324954; called by muse, mutect2, varscan2
- GALNT15 | c.253C>T p.P85S | Missense Mutation (SNP) | VAF 62/515 reads (12%) | SIFT tolerated (0.58); PolyPhen benign (0.007); catalogued as rs1359996967; called by muse, mutect2, varscan2
- GFPT1 | c.2002G>A p.V668M (on ENST00000357308 / NM_001244710.2; = p.V650M on NM_002056.4) | Missense Mutation (SNP) | VAF 141/467 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV100622989; called by muse, mutect2, varscan2
- GLIS3 | c.205G>A p.A69T | Missense Mutation (SNP) | VAF 151/700 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.434); catalogued as COSV67945442; called by muse, mutect2, varscan2
- GLS2 | c.973G>A p.G325S | Missense Mutation (SNP) | VAF 41/426 reads (10%) | SIFT tolerated (0.26); PolyPhen benign (0.159); catalogued as rs141411550; called by muse, mutect2, varscan2
- GON4L | c.4558_4560del p.E1520del | In Frame Del (DEL) | VAF 47/312 reads (15%) | catalogued as rs986292394; called by pindel, varscan2
- GP5 | c.1403del p.G468Vfs*43 | Frame Shift Del (DEL) | VAF 17/125 reads (14%) | catalogued as rs750921214; called by mutect2, pindel, varscan2
- GPR150 | c.698C>T p.A233V | Missense Mutation (SNP) | VAF 128/997 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.04); catalogued as rs1267852715; called by muse, mutect2, varscan2
- GPR152 | c.1357G>T p.G453* | Nonsense Mutation (SNP) | VAF 8/120 reads (7%) | catalogued as COSV56887473; called by muse, mutect2
- GPR179 | c.6385G>A p.A2129T (on ENST00000621958; = p.A2128T on NM_001004334.4) | Missense Mutation (SNP) | VAF 30/278 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.121); catalogued as rs764437497; called by muse, mutect2
- GPR78 | c.503G>A p.R168H | Missense Mutation (SNP) | VAF 56/503 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.095); catalogued as COSV66763822; called by muse, mutect2, varscan2
- GRIK2 | c.325C>T p.P109S | Missense Mutation (SNP) | VAF 34/270 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1478986170; called by muse, mutect2, varscan2
- GRIK5 | c.2492G>A p.R831Q | Missense Mutation (SNP) | VAF 22/163 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs781893931; called by muse, mutect2, varscan2
- GSE1 | c.366del p.V123Wfs*2 | Frame Shift Del (DEL) | VAF 45/117 reads (38%) | catalogued as rs754199513; called by mutect2, varscan2
- GSK3A | c.1021C>T p.R341W | Missense Mutation (SNP) | VAF 22/108 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs907284414; called by muse, mutect2, varscan2
- HAND2 | c.247del p.V83Cfs*16 | Frame Shift Del (DEL) | VAF 21/163 reads (13%) | catalogued as CM105646; called by mutect2, pindel, varscan2
- HAPLN3 | c.217C>T p.R73C | Missense Mutation (SNP) | VAF 37/736 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.849); catalogued as rs773440039; called by muse, mutect2
- HCN2 | c.1415C>T p.S472L | Missense Mutation (SNP) | VAF 169/628 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.625); catalogued as rs768008986; called by muse, mutect2, varscan2
- HDAC10 | c.1607C>T p.A536V | Missense Mutation (SNP) | VAF 37/355 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.013); catalogued as rs766386076; called by muse, mutect2, varscan2
- HEXIM1 | c.101del p.P34Qfs*52 | Frame Shift Del (DEL) | VAF 199/818 reads (24%) | catalogued as rs767170073; called by mutect2, pindel, varscan2
- HIPK3 | c.802C>T p.R268C | Missense Mutation (SNP) | VAF 22/218 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); catalogued as rs376939727, COSV57561140; called by muse, mutect2, varscan2
- HS3ST2 | c.53G>A p.R18H | Missense Mutation (SNP) | VAF 193/626 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.175); catalogued as rs866604120, COSV99758612; called by muse, mutect2, varscan2
- IGSF8 | c.1363G>A p.G455R | Missense Mutation (SNP) | VAF 34/880 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1460814489; called by muse, mutect2
- IL5RA | c.228+1G>A p.X76_splice | Splice Site (SNP) | VAF 9/39 reads (23%) | catalogued as rs775911773, COSV56521995; called by muse, mutect2
- INPPL1 | c.1114C>T p.R372C | Missense Mutation (SNP) | VAF 116/456 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.799); catalogued as rs754156985; called by muse, mutect2, varscan2
- INPPL1 | c.2548C>T p.Q850* | Nonsense Mutation (SNP) | VAF 24/406 reads (6%) | catalogued as rs748648191; called by muse, mutect2
- IQGAP3 | c.3632C>T p.A1211V | Missense Mutation (SNP) | VAF 22/538 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.355); catalogued as COSV63250107; called by muse, mutect2
- IQSEC2 | c.3415G>A p.A1139T (on ENST00000642864 / NM_001111125.3; = p.A934T on NM_015075.2) | Missense Mutation (SNP) | VAF 26/542 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1426916903, COSV64724962; called by muse, mutect2
- ITSN1 | c.4655G>A p.R1552Q | Missense Mutation (SNP) | VAF 41/327 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.623); catalogued as rs1408360223, COSV67157162; called by muse, mutect2, varscan2
- JAK1 | c.1289del p.P430Rfs*2 | Frame Shift Del (DEL) | VAF 26/114 reads (23%) | catalogued as rs755650243; called by mutect2, varscan2
- JPH3 | c.1060del p.L354Cfs*117 | Frame Shift Del (DEL) | VAF 111/588 reads (19%) | catalogued as COSV52470301; called by mutect2, pindel, varscan2
- KANK2 | c.1435G>A p.V479M (on ENST00000586659 / NM_001379562.1; = p.V487M on NM_015493.7 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 56/432 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.057); catalogued as rs769973461, COSV104422362; called by muse, mutect2, varscan2
- KAT2A | c.550A>G p.M184V | Missense Mutation (SNP) | VAF 104/431 reads (24%) | SIFT tolerated (0.44); PolyPhen benign (0.05); catalogued as rs1258556548; called by muse, mutect2, varscan2
- KCNB2 | c.2422G>A p.D808N | Missense Mutation (SNP) | VAF 75/340 reads (22%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.848); catalogued as COSV73049297; called by muse, mutect2, varscan2
- KCNK16 | c.583G>A p.E195K | Missense Mutation (SNP) | VAF 88/335 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100949048, COSV64678629; called by muse, mutect2, varscan2
- KIFAP3 | c.1096C>T p.R366* | Nonsense Mutation (SNP) | VAF 9/288 reads (3%) | catalogued as rs1329091443, COSV100810956; called by muse, mutect2
- KLHL34 | c.704G>A p.R235H | Missense Mutation (SNP) | VAF 69/241 reads (29%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.919); catalogued as COSV65280264; called by muse, mutect2, varscan2
- KLK7 | c.133G>A p.V45M | Missense Mutation (SNP) | VAF 94/478 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1321134550; called by muse, mutect2, varscan2
- KPRP | c.1138C>T p.P380S | Missense Mutation (SNP) | VAF 33/1017 reads (3%) | SIFT tolerated (0.1); PolyPhen benign (0.034); catalogued as rs1249262742; called by muse, mutect2
- LCT | c.827T>A p.V276D | Missense Mutation (SNP) | VAF 20/578 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); catalogued as COSV51558781; called by muse, mutect2
- LHX1 | c.1194del p.E399Kfs*2 | Frame Shift Del (DEL) | VAF 146/458 reads (32%) | catalogued as rs775423572; called by mutect2, varscan2
- LINC02210-CRHR1 | c.350G>A p.R117H | Missense Mutation (SNP) | VAF 16/391 reads (4%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.982); catalogued as rs369219844; called by muse, mutect2
- LMLN | c.557G>A p.R186Q | Missense Mutation (SNP) | VAF 24/174 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.88); catalogued as rs150151522; called by muse, varscan2
- LOXL4 | c.214C>T p.R72C | Missense Mutation (SNP) | VAF 99/921 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs775524314; called by muse, mutect2, varscan2
- LRRCC1 | c.1394A>G p.H465R | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV64485714; called by muse, varscan2
- LRRCC1 | c.3001C>T p.R1001C | Missense Mutation (SNP) | VAF 11/131 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs769047718, COSV64483169; called by muse, mutect2
- LSP1 | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 72/724 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.97); catalogued as rs772024277; called by muse, mutect2
- LVRN | c.491del p.P164Rfs*33 | Frame Shift Del (DEL) | VAF 164/688 reads (24%) | catalogued as rs746413071, COSV63497009; called by mutect2, pindel, varscan2
- LYN | c.327del p.E110Kfs*15 | Frame Shift Del (DEL) | VAF 22/179 reads (12%) | catalogued as rs1266824391, COSV99066642; called by mutect2, pindel, varscan2
- MAD1L1 | c.1888C>T p.R630C | Missense Mutation (SNP) | VAF 26/622 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1329907596, COSV99764776, COSV99766395; called by muse, mutect2
- MAD2L1 | c.545G>A p.R182H | Missense Mutation (SNP) | VAF 13/110 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.219); catalogued as rs758740535, COSV99633797; called by muse, mutect2, varscan2
- MAP9 | c.650C>T p.P217L | Missense Mutation (SNP) | VAF 43/392 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs772931614, COSV100250856; called by muse, mutect2, varscan2
- MARCKS | c.980del p.P327Qfs*42 | Frame Shift Del (DEL) | VAF 39/319 reads (12%) | catalogued as rs770972906; called by mutect2, pindel, varscan2
- MCHR2 | c.623del p.F208Sfs*5 | Frame Shift Del (DEL) | VAF 10/62 reads (16%) | catalogued as rs759525627, COSV55999002; called by mutect2, varscan2
- MED12L | c.6076G>A p.G2026R | Missense Mutation (SNP) | VAF 37/145 reads (26%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as rs142023200, COSV99072075; called by muse, mutect2, varscan2
- MEGF8 | c.1315C>T p.R439W | Missense Mutation (SNP) | VAF 23/213 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs769862975; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MN1 | c.3407G>A p.R1136H | Missense Mutation (SNP) | VAF 41/325 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV56556844; called by muse, mutect2, varscan2
- MOCOS | c.*6del | Frame Shift Del (DEL) | VAF 36/242 reads (15%) | catalogued as rs755830405; called by mutect2, varscan2
- MSL2 | c.988G>A p.A330T | Missense Mutation (SNP) | VAF 58/560 reads (10%) | SIFT tolerated (0.37); PolyPhen benign (0.007); catalogued as COSV53866835; called by muse, mutect2, varscan2
- MYH10 | c.2386G>A p.V796I | Missense Mutation (SNP) | VAF 32/132 reads (24%) | SIFT tolerated (0.39); PolyPhen benign (0.022); catalogued as rs755114317, COSV52604684; called by muse, mutect2, varscan2
- MYO15B | c.8143_8145del p.E2715del | In Frame Del (DEL) | VAF 54/408 reads (13%) | catalogued as rs750098885; called by mutect2, pindel, varscan2
- MYOCD | c.1440del p.S481Pfs*18 | Frame Shift Del (DEL) | VAF 40/371 reads (11%) | catalogued as COSV58513333; called by mutect2, pindel, varscan2
- NDST1 | c.1447C>T p.R483W | Missense Mutation (SNP) | VAF 41/275 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1484836650, COSV55784704, COSV55786084; called by muse, mutect2, varscan2
- NDUFB10 | c.409+5G>A | Splice Region (SNP) | VAF 90/345 reads (26%) | catalogued as rs769595304, COSV51909721; called by mutect2, varscan2
- NKD2 | c.797C>A p.P266H | Missense Mutation (SNP) | VAF 14/136 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99724319; called by muse, mutect2
- NMUR1 | c.872G>A p.G291D | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT tolerated (0.31); PolyPhen benign (0.014); catalogued as rs1214113010, COSV59404724; called by muse, mutect2, varscan2
- NOP53 | c.941G>A p.G314D | Missense Mutation (SNP) | VAF 18/169 reads (11%) | SIFT tolerated (0.72); PolyPhen possibly damaging (0.602); catalogued as rs551821723; called by muse, mutect2, varscan2
- NPAT | c.631C>T p.R211C | Missense Mutation (SNP) | VAF 19/452 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99586447; called by muse, mutect2
- NPHP4 | c.2866G>A p.A956T | Missense Mutation (SNP) | VAF 112/414 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.045); catalogued as rs369624442; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ODAPH | c.307C>T p.P103S | Missense Mutation (SNP) | VAF 42/856 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs1208645424; called by muse, mutect2
- OR10H3 | c.791C>A p.P264H | Missense Mutation (SNP) | VAF 37/468 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as rs760384349; called by muse, mutect2
- OTOP1 | c.1160G>A p.R387H | Missense Mutation (SNP) | VAF 36/672 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs747230871, COSV56394023; called by muse, mutect2
- OVCA2 | c.46C>T p.R16W | Missense Mutation (SNP) | VAF 56/498 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753224058; called by muse, mutect2, varscan2
- PACSIN2 | c.907-1G>T p.X303_splice | Splice Site (SNP) | VAF 18/178 reads (10%) | catalogued as COSV54319155; called by muse, mutect2
- PAGE4 | c.257C>T p.P86L | Missense Mutation (SNP) | VAF 18/351 reads (5%) | SIFT tolerated (1); PolyPhen possibly damaging (0.727); catalogued as COSV54334680, COSV99489855; called by muse, mutect2
- PALB2 | c.2743G>A p.A915T | Missense Mutation (SNP) | VAF 62/609 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs374736398; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- PCDH15 | c.3679G>A p.D1227N | Missense Mutation (SNP) | VAF 118/621 reads (19%) | SIFT tolerated (0.96); PolyPhen benign (0.02); catalogued as rs368127988, COSV100217129; ClinVar: uncertain significance; called by muse, varscan2
- PCDH19 | c.1184G>A p.R395Q | Missense Mutation (SNP) | VAF 179/640 reads (28%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.997); catalogued as COSV55258803; called by muse, mutect2, varscan2
- PCDH19 | c.539C>T p.T180M | Missense Mutation (SNP) | VAF 30/1020 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99720326; called by muse, mutect2
- PDE6A | c.568G>A p.A190T | Missense Mutation (SNP) | VAF 56/473 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV54927914; called by muse, mutect2, varscan2
- PHETA1 | c.329G>A p.R110H | Missense Mutation (SNP) | VAF 33/258 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs757589490, COSV64058676; called by muse, mutect2, varscan2
- PITPNA | c.239C>T p.A80V | Missense Mutation (SNP) | VAF 8/172 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.331); catalogued as COSV100541480; called by muse, mutect2
- PKD1 | c.2087C>T p.A696V | Missense Mutation (SNP) | VAF 16/319 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.306); catalogued as rs1357251741, COSV51911588; called by muse, mutect2
- PKNOX2 | c.47C>T p.T16M | Missense Mutation (SNP) | VAF 85/274 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as rs1482680829; called by muse, mutect2, varscan2
- PLCG1 | c.2657G>A p.R886H | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as rs761873798, COSV54817120; called by muse, mutect2, varscan2
- PLXNB2 | c.4172G>A p.R1391H | Missense Mutation (SNP) | VAF 20/140 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1431309803, COSV100833884; called by muse, mutect2
- PPFIA3 | c.1172G>A p.R391H | Missense Mutation (SNP) | VAF 62/601 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1303317185; called by muse, mutect2, varscan2
- PPP2R3B | c.544C>T p.L182F | Missense Mutation (SNP) | VAF 47/194 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.762); catalogued as rs1278443664; called by muse, mutect2, varscan2
- PREX2 | c.1580G>A p.R527H | Missense Mutation (SNP) | VAF 42/376 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.879); catalogued as rs767992923, COSV55791056; called by muse, mutect2, varscan2
- PRKCG | c.1201C>T p.R401C | Missense Mutation (SNP) | VAF 81/806 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1367827846; called by muse, mutect2
- PTH1R | c.136G>A p.A46T | Missense Mutation (SNP) | VAF 40/448 reads (9%) | SIFT tolerated (0.31); PolyPhen benign (0.165); catalogued as rs201320537; called by muse, mutect2
- PTP4A3 | c.514G>A p.V172I (on ENST00000329397; = p.V147I on NM_007079.3) | Missense Mutation (SNP) | VAF 34/387 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs770184810; called by muse, mutect2
- PTPRO | c.145G>A p.V49I | Missense Mutation (SNP) | VAF 62/281 reads (22%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as rs368110581; called by muse, mutect2, varscan2
- PUF60 | c.590del p.G197Afs*12 (on ENST00000526683 / NM_001362896.2; = p.G180Afs*12 on NM_014281.5 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 49/435 reads (11%) | catalogued as COSV100252546; called by mutect2, pindel, varscan2
- PXDN | c.2770C>T p.R924C | Missense Mutation (SNP) | VAF 80/261 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.846); catalogued as rs780029685; called by muse, mutect2, varscan2
- PYCR2 | c.508G>A p.V170I | Missense Mutation (SNP) | VAF 181/843 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.009); catalogued as rs779789219; called by muse, mutect2, varscan2
- RABGAP1L | c.2025G>T p.Q675H | Missense Mutation (SNP) | VAF 9/120 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV52319979; called by muse, mutect2
- RAD50 | c.2522C>T p.T841I | Missense Mutation (SNP) | VAF 22/273 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.736); catalogued as rs759267791; ClinVar: uncertain significance; called by muse, mutect2
- RBP3 | c.2381C>T p.P794L | Missense Mutation (SNP) | VAF 231/1294 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782530735; called by muse, mutect2, varscan2
- REEP4 | c.763G>A p.V255M | Missense Mutation (SNP) | VAF 74/667 reads (11%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); catalogued as rs749573650, COSV57942117; called by muse, mutect2, varscan2
- RNF112 | c.13G>A p.A5T | Missense Mutation (SNP) | VAF 51/434 reads (12%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.003); catalogued as rs1174755205, COSV71978945; called by muse, mutect2, varscan2
- RNPEP | c.1552G>T p.D518Y | Missense Mutation (SNP) | VAF 36/730 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV55241211; called by muse, mutect2
- RNPEPL1 | c.173C>T p.A58V | Missense Mutation (SNP) | VAF 13/132 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.012); catalogued as rs1374287916; called by muse, mutect2, varscan2
- ROBO3 | c.1646dup p.T550Yfs*17 | Frame Shift Ins (INS) | VAF 14/146 reads (10%) | catalogued as rs773719165; called by mutect2, pindel
- RPAP1 | c.3391C>T p.R1131W | Missense Mutation (SNP) | VAF 112/359 reads (31%) | SIFT tolerated (0.23); PolyPhen benign (0.02); catalogued as rs866714971, COSV58537132; called by muse, mutect2, varscan2
- RPUSD1 | c.445G>A p.V149M | Missense Mutation (SNP) | VAF 123/452 reads (27%) | SIFT tolerated (0.27); PolyPhen benign (0.035); catalogued as rs754419281, COSV99136053; called by muse, mutect2, varscan2
- RUBCN | c.830del p.P277Qfs*7 | Frame Shift Del (DEL) | VAF 32/147 reads (22%) | catalogued as rs745498865, COSV56364590; called by mutect2, pindel, varscan2
- RUNX1 | c.470C>T p.P157L (on ENST00000344691 / NM_001001890.3; = p.P184L on NM_001754.5) | Missense Mutation (SNP) | VAF 71/596 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55875710; called by muse, mutect2, varscan2
- RUSC2 | c.2597G>A p.R866Q | Missense Mutation (SNP) | VAF 67/598 reads (11%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.644); catalogued as rs367899388; called by muse, mutect2, varscan2
- SAFB | c.1987C>T p.R663C | Missense Mutation (SNP) | VAF 188/1494 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52649995; called by muse, mutect2, varscan2
- SASH1 | c.3177del p.W1060Gfs*16 | Frame Shift Del (DEL) | VAF 38/359 reads (11%) | catalogued as rs761606832; called by mutect2, pindel, varscan2
- SEPHS1 | c.787G>A p.A263T | Missense Mutation (SNP) | VAF 30/758 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1164623526; called by muse, mutect2
- SERPINB6 | c.205G>A p.A69T (on ENST00000612421 / NM_001271823.2; = p.A50T on NM_004568.6) | Missense Mutation (SNP) | VAF 34/544 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.54); catalogued as rs144890174; called by muse, mutect2
- SERPINF2 | c.1208G>A p.R403H | Missense Mutation (SNP) | VAF 176/640 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779114899, COSV60664338; called by muse, mutect2, varscan2
- SETD3 | c.152T>C p.V51A | Missense Mutation (SNP) | VAF 67/314 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as rs1339425425; called by muse, mutect2, varscan2
- SFI1 | c.1195G>A p.A399T | Missense Mutation (SNP) | VAF 30/258 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs561440006, COSV66290668; called by muse, mutect2, varscan2
- SIX3 | c.436C>T p.R146C | Missense Mutation (SNP) | VAF 200/1482 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as rs756395470; called by muse, mutect2, varscan2
- SLC16A14 | c.169C>A p.L57I | Missense Mutation (SNP) | VAF 46/336 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99725430; called by muse, mutect2, varscan2
- SLC2A10 | c.865G>T p.G289W | Missense Mutation (SNP) | VAF 20/462 reads (4%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.819); catalogued as COSV100826356, COSV63714927; called by muse, mutect2
- SLC6A18 | c.293G>A p.S98N | Missense Mutation (SNP) | VAF 48/374 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.026); catalogued as rs775308596; called by muse, mutect2, varscan2
- SLC9A5 | c.2555G>A p.R852H | Missense Mutation (SNP) | VAF 54/183 reads (30%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as rs778613956, COSV100237113; called by muse, mutect2, varscan2
- SLCO5A1 | c.1928G>T p.R643L | Missense Mutation (SNP) | VAF 98/423 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV52655934; called by muse, mutect2, varscan2
- SMARCA2 | c.4331G>A p.R1444K | Missense Mutation (SNP) | VAF 34/255 reads (13%) | SIFT tolerated (0.93); PolyPhen probably damaging (0.97); catalogued as rs768201532; called by muse, mutect2, varscan2
- SNX20 | c.470G>A p.R157H | Missense Mutation (SNP) | VAF 62/516 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56057901; called by muse, mutect2, varscan2
- SPTAN1 | c.1352C>T p.A451V | Missense Mutation (SNP) | VAF 78/960 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.294); catalogued as rs149336930, COSV63989073; called by muse, mutect2
- SRL | c.536C>A p.P179H | Missense Mutation (SNP) | VAF 44/358 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68422867; called by muse, mutect2, varscan2
- SSH2 | c.2756dup p.E920Rfs*22 | Frame Shift Ins (INS) | VAF 28/110 reads (25%) | catalogued as rs752567808; called by mutect2, varscan2
- ST6GALNAC4 | c.883G>A p.A295T | Missense Mutation (SNP) | VAF 18/109 reads (17%) | PolyPhen benign (0.011); catalogued as rs773204572, COSV59130190; called by muse, mutect2, varscan2
- ST8SIA6 | c.753del p.A252Pfs*53 | Frame Shift Del (DEL) | VAF 16/140 reads (11%) | catalogued as rs758746672, COSV66468613; called by mutect2, varscan2
- STK40 | c.134C>T p.P45L | Missense Mutation (SNP) | VAF 61/237 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63734959; called by muse, mutect2, varscan2
- TAF1C | c.2062C>T p.R688* | Nonsense Mutation (SNP) | VAF 51/179 reads (28%) | catalogued as rs1229037446; called by muse, mutect2, varscan2
- TBXT | c.1140del p.A381Rfs*44 | Frame Shift Del (DEL) | VAF 90/392 reads (23%) | catalogued as COSV99752171; called by mutect2, pindel, varscan2
- TCIRG1 | c.1351G>A p.G451S | Missense Mutation (SNP) | VAF 63/587 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.951); catalogued as rs533323966, COSV55836906; called by muse, mutect2, varscan2
- TDP2 | c.428A>G p.Y143C | Missense Mutation (SNP) | VAF 32/111 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs1485863094; called by muse, varscan2
- TGFBR3 | c.2059C>T p.R687* | Nonsense Mutation (SNP) | VAF 132/474 reads (28%) | catalogued as rs769971153, COSV99282391; called by muse, mutect2, varscan2
- THEMIS2 | c.1652dup p.P552Tfs*5 | Frame Shift Ins (INS) | VAF 66/278 reads (24%) | catalogued as rs750840849; called by mutect2, varscan2
- TIAM2 | c.974C>T p.T325M | Missense Mutation (SNP) | VAF 112/443 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.259); catalogued as rs374348209; called by muse, mutect2, varscan2
- TLE1 | c.1852G>T p.G618* | Nonsense Mutation (SNP) | VAF 26/214 reads (12%) | catalogued as COSV64719361, COSV64719460, COSV64723155; called by muse, mutect2, varscan2
- TMCO3 | c.1949C>T p.T650M | Missense Mutation (SNP) | VAF 200/600 reads (33%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.82); catalogued as rs767140405; called by muse, mutect2, varscan2
- TMEM121 | c.721C>T p.R241W | Missense Mutation (SNP) | VAF 30/695 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.432); catalogued as rs781857279, COSV66796623; called by muse, mutect2
- TMEM219 | c.365C>T p.A122V | Missense Mutation (SNP) | VAF 12/234 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54244438; called by muse, mutect2
- TMEM37 | c.145C>T p.H49Y | Missense Mutation (SNP) | VAF 69/686 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs758578873, COSV50028344; called by muse, mutect2, varscan2
- TNRC6C | c.1969del p.E657Rfs*3 | Frame Shift Del (DEL) | VAF 41/153 reads (27%) | catalogued as COSV56953297; called by mutect2, pindel, varscan2
- TOGARAM2 | c.2950C>A p.Q984K | Missense Mutation (SNP) | VAF 54/728 reads (7%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.714); catalogued as COSV99058966; called by muse, mutect2
- TRABD2A | c.1162G>A p.A388T (on ENST00000409520 / NM_001277053.2; = p.A339T on NM_001080824.3) | Missense Mutation (SNP) | VAF 24/778 reads (3%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0); catalogued as COSV52884849; called by muse, mutect2
- TRERF1 | c.3400A>G p.R1134G | Missense Mutation (SNP) | VAF 60/664 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV61667902; called by muse, mutect2
- TRIM10 | c.1120G>A p.A374T | Missense Mutation (SNP) | VAF 12/303 reads (4%) | SIFT tolerated (0.15); PolyPhen benign (0.371); catalogued as COSV100939676; called by muse, mutect2
- TRPM5 | c.1714C>T p.R572C | Missense Mutation (SNP) | VAF 122/430 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); catalogued as rs374622020, COSV50144287; called by muse, mutect2, varscan2
- TSPYL4 | c.182del p.G61Vfs*71 | Frame Shift Del (DEL) | VAF 36/134 reads (27%) | catalogued as COSV60310254; called by mutect2, varscan2
- TTN | c.42614C>T p.A14205V (on ENST00000591111; = p.A6781V on NM_003319.4) | Missense Mutation (SNP) | VAF 35/564 reads (6%) | PolyPhen benign (0.154); catalogued as rs1183139911; ClinVar: uncertain significance; called by muse, mutect2
- TUBA3C | c.1080dup p.T361Hfs*34 | Frame Shift Ins (INS) | VAF 42/328 reads (13%) | catalogued as rs750889205; called by mutect2, pindel
- TUBE1 | c.512A>G p.Y171C | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.111); catalogued as rs1257858189; called by muse, mutect2, varscan2
- UBE2C | c.217-1G>T p.X73_splice | Splice Site (SNP) | VAF 22/464 reads (5%) | catalogued as COSV54754857; called by muse, mutect2
- UGT1A5 | c.44G>A p.G15E | Missense Mutation (SNP) | VAF 40/494 reads (8%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.827); catalogued as COSV59388442; called by muse, mutect2
- UNC5D | c.2711T>C p.L904P | Missense Mutation (SNP) | VAF 173/675 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54773513; called by muse, mutect2, varscan2
- USP21 | c.113G>A p.R38H | Missense Mutation (SNP) | VAF 173/940 reads (18%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); catalogued as rs372804422, COSV57089256; called by muse, mutect2, varscan2
- USP42 | c.2368G>A p.A790T | Missense Mutation (SNP) | VAF 48/165 reads (29%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs1296416712, COSV100084367; called by muse, mutect2, varscan2
- VAV2 | c.1838C>T p.T613M (on ENST00000371850 / NM_001134398.2; = p.T603M on NM_003371.4) | Missense Mutation (SNP) | VAF 126/558 reads (23%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.775); catalogued as rs774081477; called by muse, mutect2
- VCPKMT | c.672dup p.S225Ifs*22 | Frame Shift Ins (INS) | VAF 26/127 reads (20%) | catalogued as rs1264097962; called by mutect2, pindel, varscan2
- WIZ | c.3076C>T p.P1026S (on ENST00000673675 / NM_001371589.1; = p.P203S on NM_001330395.4) | Missense Mutation (SNP) | VAF 19/419 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.025); catalogued as rs1295178760, COSV54611484; called by muse, mutect2
- WNT5B | c.1057G>A p.V353M | Missense Mutation (SNP) | VAF 24/264 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.727); catalogued as rs1447197412; called by muse, mutect2
- XG | c.331G>A p.G111S | Missense Mutation (SNP) | VAF 16/366 reads (4%) | SIFT tolerated (0.59); PolyPhen benign (0.007); catalogued as rs1162697625; called by muse, mutect2
- XRCC1 | c.322G>A p.V108I | Missense Mutation (SNP) | VAF 41/438 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.283); catalogued as rs1345722388, COSV99486580; called by muse, mutect2, varscan2
- ZAN | c.545G>A p.R182Q | Missense Mutation (SNP) | VAF 35/167 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.796); catalogued as rs752952727; called by muse, mutect2, varscan2
- ZBED4 | c.1775C>T p.P592L | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.716); catalogued as rs148466799; called by muse, mutect2, varscan2
- ZFHX3 | c.9812C>T p.T3271M | Missense Mutation (SNP) | VAF 171/564 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.379); catalogued as rs759418149, COSV51723989; called by muse, mutect2, varscan2
- ZFX | c.587T>C p.I196T | Missense Mutation (SNP) | VAF 46/155 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs1387951096; called by muse, mutect2, varscan2
- ZNF425 | c.703C>T p.R235W | Missense Mutation (SNP) | VAF 52/553 reads (9%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV100955618; called by muse, mutect2
- ZNF608 | c.1393del p.A465Pfs*46 | Frame Shift Del (DEL) | VAF 41/264 reads (16%) | catalogued as rs764779166; called by mutect2, pindel, varscan2
- ABCA13 | c.3344G>A p.S1115N | Missense Mutation (SNP) | VAF 27/305 reads (9%) | SIFT tolerated (0.36); PolyPhen benign (0.001); called by muse, mutect2
- ABCC10 | c.68A>G p.D23G | Missense Mutation (SNP) | VAF 158/623 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ABCC8 | c.1432G>T p.A478S | Missense Mutation (SNP) | VAF 23/614 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.19); called by muse, mutect2
- ACAP1 | c.208G>T p.G70C | Missense Mutation (SNP) | VAF 42/475 reads (9%) | SIFT tolerated (0.77); PolyPhen benign (0); called by muse, mutect2
- ACIN1 | c.3929G>A p.R1310Q | Missense Mutation (SNP) | VAF 64/576 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.953); called by muse, varscan2
- ACO1 | c.1021G>T p.G341* | Nonsense Mutation (SNP) | VAF 10/228 reads (4%) | called by muse, mutect2
- ACTR2 | c.356del p.N119Tfs*6 | Frame Shift Del (DEL) | VAF 14/102 reads (14%) | called by mutect2, pindel
- ADA2 | c.888A>C p.K296N (on ENST00000262607; = p.K55N on NM_177405.3) | Missense Mutation (SNP) | VAF 14/362 reads (4%) | SIFT tolerated (0.31); PolyPhen benign (0.129); called by muse, mutect2
- ADCK5 | c.67C>T p.P23S | Missense Mutation (SNP) | VAF 9/204 reads (4%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0.149); called by muse, mutect2
- ADGRA2 | c.3295C>A p.L1099M | Missense Mutation (SNP) | VAF 24/286 reads (8%) | SIFT tolerated (0.26); PolyPhen benign (0.101); called by muse, mutect2
- ADGRL3 | c.2047G>C p.D683H (on ENST00000506720 / NM_001322402.2; = p.D615H on NM_015236.6) | Missense Mutation (SNP) | VAF 61/234 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- ADNP2 | c.1835T>C p.I612T | Missense Mutation (SNP) | VAF 64/462 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- AGAP3 | c.1682G>A p.S561N (on ENST00000622464; = p.S597N on NM_031946.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/107 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- AGO3 | c.1270C>T p.R424W | Missense Mutation (SNP) | VAF 9/109 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); called by muse, mutect2
- ALDH6A1 | c.877A>G p.M293V | Missense Mutation (SNP) | VAF 115/672 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.338); called by muse, mutect2, varscan2
- ALDOB | c.133C>T p.Q45* | Nonsense Mutation (SNP) | VAF 29/414 reads (7%) | called by muse, mutect2
- ALS2 | c.3185G>A p.G1062E | Missense Mutation (SNP) | VAF 144/640 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AMER3 | c.1951C>A p.L651M | Missense Mutation (SNP) | VAF 17/419 reads (4%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.725); called by muse, mutect2
- AMPD3 | c.680del p.G227Afs*32 (on ENST00000396553 / NM_001025389.2; = p.G236Afs*32 on NM_000480.3) | Frame Shift Del (DEL) | VAF 55/448 reads (12%) | called by mutect2, pindel, varscan2
- ANKRD31 | c.2771G>A p.G924D | Missense Mutation (SNP) | VAF 12/140 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.019); called by muse, mutect2
- ANKRD34A | c.217G>A p.A73T | Missense Mutation (SNP) | VAF 22/153 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.166); called by muse, mutect2, varscan2
- AP5S1 | c.341G>A p.W114* | Nonsense Mutation (SNP) | VAF 42/1244 reads (3%) | called by muse, mutect2
- APEX2 | c.1466G>A p.G489D | Missense Mutation (SNP) | VAF 26/254 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- ARAF | c.763del p.R255Gfs*37 | Frame Shift Del (DEL) | VAF 59/247 reads (24%) | called by mutect2, pindel, varscan2
- ARAP3 | c.15G>T p.Q5H | Missense Mutation (SNP) | VAF 9/192 reads (5%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.503); called by muse, mutect2
- AREL1 | c.2178G>A p.W726* | Nonsense Mutation (SNP) | VAF 50/229 reads (22%) | called by muse, mutect2, varscan2
- ARHGAP23 | c.2452A>G p.N818D | Missense Mutation (SNP) | VAF 28/323 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.113); called by muse, mutect2
- ARPC5 | c.160G>A p.A54T | Missense Mutation (SNP) | VAF 21/162 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); called by muse, varscan2
- ARSL | c.830A>G p.Q277R | Missense Mutation (SNP) | VAF 113/387 reads (29%) | SIFT tolerated (0.56); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ATAD3B | c.826G>C p.A276P (on ENST00000308647; = p.A382P on NM_031921.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 52/712 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); called by muse, mutect2
- ATP2A1 | c.2872A>G p.K958E | Missense Mutation (SNP) | VAF 187/700 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ATP6V0A1 | c.1235A>G p.H412R | Missense Mutation (SNP) | VAF 19/359 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- ATP8B1 | c.1474-1G>A p.X492_splice | Splice Site (SNP) | VAF 35/282 reads (12%) | called by muse, mutect2, varscan2
- B3GAT3 | c.655G>T p.G219W | Missense Mutation (SNP) | VAF 35/642 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- B9D2 | c.89G>T p.G30V | Missense Mutation (SNP) | VAF 32/398 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- BDP1 | c.1727C>T p.A576V | Missense Mutation (SNP) | VAF 45/171 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- BICD1 | c.962T>C p.L321P | Missense Mutation (SNP) | VAF 16/127 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); called by muse, mutect2, varscan2
- BMP1 | c.722T>G p.I241S | Missense Mutation (SNP) | VAF 52/186 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- BRAP | c.668G>A p.G223D | Missense Mutation (SNP) | VAF 12/240 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- BRD4 | c.2729A>G p.Q910R | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.051); called by muse, varscan2
- BRINP2 | c.1654C>A p.L552I | Missense Mutation (SNP) | VAF 10/245 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.094); called by muse, mutect2
- BTG3 | c.659del p.N220Ifs*9 | Frame Shift Del (DEL) | VAF 25/247 reads (10%) | called by mutect2, pindel, varscan2
- BUD31 | c.281del p.K94Sfs*102 | Frame Shift Del (DEL) | VAF 23/116 reads (20%) | called by mutect2, pindel, varscan2
- C17orf75 | c.464del p.L155* | Frame Shift Del (DEL) | VAF 22/210 reads (10%) | called by mutect2, pindel
- C1orf87 | c.463G>T p.G155C | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.799); called by muse, mutect2, varscan2
- C2orf42 | c.1del p.M1? | Frame Shift Del (DEL) | VAF 11/92 reads (12%) | called by mutect2, pindel, varscan2
- C8orf76 | c.641T>A p.L214* | Nonsense Mutation (SNP) | VAF 98/335 reads (29%) | called by muse, mutect2, varscan2
- C9orf72 | c.1123A>G p.T375A | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.081); called by muse, mutect2
- CABP1 | c.443C>T p.A148V | Missense Mutation (SNP) | VAF 9/96 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CACNB4 | c.145C>A p.Q49K | Missense Mutation (SNP) | VAF 62/184 reads (34%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.761); called by muse, mutect2, varscan2
- CACNG8 | c.31C>T p.R11W | Missense Mutation (SNP) | VAF 74/356 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); called by muse, mutect2
- CAND2 | c.1687C>T p.P563S (on ENST00000456430 / NM_001162499.2; = p.P470S on NM_012298.3) | Missense Mutation (SNP) | VAF 169/599 reads (28%) | SIFT tolerated (0.4); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- CAPN3 | c.553T>C p.Y185H | Missense Mutation (SNP) | VAF 100/926 reads (11%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- CAPN9 | c.1370A>G p.D457G | Missense Mutation (SNP) | VAF 113/1224 reads (9%) | SIFT tolerated (0.54); PolyPhen benign (0); called by muse, mutect2
- CASK | c.2659G>A p.A887T (on ENST00000378163 / NM_001367721.1; = p.A882T on NM_003688.3) | Missense Mutation (SNP) | VAF 65/235 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.312); called by muse, mutect2, varscan2
- CCDC180 | c.2717C>T p.A906V | Missense Mutation (SNP) | VAF 22/282 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.636); called by muse, mutect2
- CD44 | c.2149T>C p.S717P | Missense Mutation (SNP) | VAF 67/275 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CDKAL1 | c.1601C>T p.A534V | Missense Mutation (SNP) | VAF 43/171 reads (25%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- CELSR1 | c.1841del p.G614Afs*54 | Frame Shift Del (DEL) | VAF 27/261 reads (10%) | called by mutect2, pindel, varscan2
- CEP162 | c.124A>G p.K42E | Missense Mutation (SNP) | VAF 41/205 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.561); called by muse, mutect2, varscan2
- CFAP47 | c.5410C>A p.P1804T | Missense Mutation (SNP) | VAF 15/125 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CFAP65 | c.4360A>G p.S1454G | Missense Mutation (SNP) | VAF 10/130 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.234); called by muse, mutect2
- CIITA | c.671A>C p.E224A | Missense Mutation (SNP) | VAF 29/964 reads (3%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- CLCN2 | c.2006del p.P669Lfs*9 | Frame Shift Del (DEL) | VAF 196/812 reads (24%) | called by mutect2, pindel, varscan2
- CLEC18A | c.109G>A p.A37T | Missense Mutation (SNP) | VAF 102/1645 reads (6%) | SIFT tolerated (0.21); PolyPhen benign (0.039); called by muse, mutect2
- CMSS1 | c.640G>A p.G214R | Missense Mutation (SNP) | VAF 70/307 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- CNTN3 | c.136del p.I46* | Frame Shift Del (DEL) | VAF 27/161 reads (17%) | called by mutect2, pindel, varscan2
- COL15A1 | c.214G>A p.G72S | Missense Mutation (SNP) | VAF 56/992 reads (6%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.928); called by muse, mutect2
- COL4A1 | c.2643G>A p.M881I | Missense Mutation (SNP) | VAF 46/866 reads (5%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.758); called by muse, mutect2
- CPT2 | c.341-3del | Splice Region (DEL) | VAF 61/302 reads (20%) | called by mutect2, pindel, varscan2
- CPXCR1 | c.285del p.I96Ffs*11 | Frame Shift Del (DEL) | VAF 44/194 reads (23%) | called by mutect2, pindel, varscan2
- CXXC1 | c.1931A>T p.D644V | Missense Mutation (SNP) | VAF 62/471 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- DENND2B | c.3228del p.F1076Lfs*16 | Frame Shift Del (DEL) | VAF 98/445 reads (22%) | called by mutect2, pindel, varscan2
- DIP2C | c.520T>C p.S174P | Missense Mutation (SNP) | VAF 28/672 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.007); called by muse, mutect2
- DIPK1B | c.648G>C p.E216D | Missense Mutation (SNP) | VAF 241/936 reads (26%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.752); called by muse, mutect2, varscan2
- DLEU7 | c.92G>T p.G31V | Missense Mutation (SNP) | VAF 23/347 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.014); called by muse, mutect2
- DLGAP4 | c.694C>A p.R232S | Missense Mutation (SNP) | VAF 66/495 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- DMGDH | c.1346_1347del p.Y449Wfs*10 | Frame Shift Del (DEL) | VAF 38/268 reads (14%) | called by pindel, varscan2
- DNAI2 | c.416C>T p.A139V | Missense Mutation (SNP) | VAF 175/640 reads (27%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- DRD1 | c.440C>T p.A147V | Missense Mutation (SNP) | VAF 26/420 reads (6%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.817); called by muse, mutect2
- DVL1 | c.1968del p.P657Hfs*17 (on ENST00000378888 / NM_001330311.2; = p.P632Hfs*17 on NM_004421.3) | Frame Shift Del (DEL) | VAF 22/226 reads (10%) | called by mutect2, pindel
- EGR3 | c.118A>G p.S40G | Missense Mutation (SNP) | VAF 42/420 reads (10%) | SIFT tolerated (0.45); PolyPhen benign (0); called by muse, mutect2
- ESYT3 | c.2624+2dup p.X875_splice | Splice Site (INS) | VAF 23/103 reads (22%) | called by mutect2, pindel, varscan2
- EXTL1 | c.1204dup p.Q402Pfs*15 | Frame Shift Ins (INS) | VAF 44/262 reads (17%) | called by mutect2, pindel, varscan2
- FAM117A | c.900del p.N301Tfs*63 | Frame Shift Del (DEL) | VAF 80/289 reads (28%) | called by mutect2, pindel, varscan2
- FAM171B | c.698C>T p.T233I | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT tolerated (0.23); PolyPhen benign (0.351); called by muse, mutect2, varscan2
- FAM200B | c.936del p.K312Nfs*3 | Frame Shift Del (DEL) | VAF 29/143 reads (20%) | called by mutect2, pindel, varscan2
- FASLG | c.599A>G p.Q200R | Missense Mutation (SNP) | VAF 33/370 reads (9%) | SIFT tolerated (0.25); PolyPhen benign (0.001); called by muse, mutect2
- FAT2 | c.790C>A p.P264T | Missense Mutation (SNP) | VAF 36/323 reads (11%) | SIFT tolerated (0.48); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FAT3 | c.6713G>T p.G2238V | Missense Mutation (SNP) | VAF 16/280 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- FLG2 | c.4243A>G p.R1415G | Missense Mutation (SNP) | VAF 37/781 reads (5%) | SIFT tolerated (0.51); PolyPhen benign (0); called by muse, mutect2
- FLNA | c.7529G>A p.S2510N (on ENST00000369850 / NM_001110556.2; = p.S2502N on NM_001456.3) | Missense Mutation (SNP) | VAF 130/961 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- FLT3 | c.1258G>A p.A420T | Missense Mutation (SNP) | VAF 24/312 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.176); called by muse, mutect2
- FOXH1 | c.707del p.G236Efs*55 | Frame Shift Del (DEL) | VAF 11/106 reads (10%) | called by mutect2, pindel, varscan2
- FOXL1 | c.439C>T p.P147S | Missense Mutation (SNP) | VAF 243/957 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- FRG1 | c.318-2A>T p.X106_splice | Splice Site (SNP) | VAF 10/112 reads (9%) | called by muse, mutect2
- FSIP2 | c.6344C>T p.T2115I | Missense Mutation (SNP) | VAF 19/188 reads (10%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.711); called by muse, mutect2, varscan2
- FSIP2 | c.8060C>T p.A2687V | Missense Mutation (SNP) | VAF 11/186 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0.015); called by muse, mutect2
- FXR2 | c.1619del p.P540Qfs*32 | Frame Shift Del (DEL) | VAF 36/307 reads (12%) | called by mutect2, varscan2
- GABRA3 | c.1027G>A p.A343T | Missense Mutation (SNP) | VAF 78/268 reads (29%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- GAP43 | c.482C>T p.A161V | Missense Mutation (SNP) | VAF 49/334 reads (15%) | SIFT tolerated (0.38); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- GDPD2 | c.1143G>T p.R381S | Missense Mutation (SNP) | VAF 41/272 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GET3 | c.328G>T p.G110C | Missense Mutation (SNP) | VAF 30/288 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); called by muse, mutect2
- GFRA2 | c.110del p.P37Qfs*63 | Frame Shift Del (DEL) | VAF 77/641 reads (12%) | called by mutect2, pindel, varscan2
- GGTLC2 | c.361-5C>T | Splice Region (SNP) | VAF 135/1217 reads (11%) | called by muse, mutect2, varscan2
- GLI4 | c.353G>T p.G118V | Missense Mutation (SNP) | VAF 27/482 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.147); called by muse, mutect2
- GOLGA8M | c.721T>C p.Y241H | Missense Mutation (SNP) | VAF 89/504 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.29); called by muse, mutect2, varscan2
- GPR149 | c.1067C>A p.T356N | Missense Mutation (SNP) | VAF 29/359 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.017); called by muse, mutect2
- GPR179 | c.5881T>C p.W1961R (on ENST00000621958; = p.W1960R on NM_001004334.4) | Missense Mutation (SNP) | VAF 42/439 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.012); called by muse, mutect2
- GPX1 | c.249T>A p.H83Q | Missense Mutation (SNP) | VAF 100/402 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); called by muse, varscan2
- GRAMD1A | c.953del p.P318Rfs*26 | Frame Shift Del (DEL) | VAF 193/768 reads (25%) | called by mutect2, pindel, varscan2
- GRM7 | c.1149del p.E384Kfs*28 | Frame Shift Del (DEL) | VAF 26/252 reads (10%) | called by mutect2, pindel
- GRTP1 | c.221G>A p.R74H | Missense Mutation (SNP) | VAF 33/339 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GSX1 | c.677C>A p.P226Q | Missense Mutation (SNP) | VAF 52/196 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.123); called by muse, varscan2
- GUCY2C | c.2013G>T p.Q671H | Missense Mutation (SNP) | VAF 37/245 reads (15%) | SIFT tolerated (0.39); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- GUCY2F | c.2197G>A p.V733I | Missense Mutation (SNP) | VAF 18/360 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0.268); called by muse, mutect2
- H3C10 | c.22G>A p.A8T | Missense Mutation (SNP) | VAF 149/599 reads (25%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- HACE1 | c.2180del p.G727Vfs*6 | Frame Shift Del (DEL) | VAF 30/290 reads (10%) | called by mutect2, pindel, varscan2
- HAPLN4 | c.508del p.R170Vfs*7 | Frame Shift Del (DEL) | VAF 20/194 reads (10%) | called by mutect2, pindel, varscan2
- HEATR1 | c.4647-2A>G p.X1549_splice | Splice Site (SNP) | VAF 26/164 reads (16%) | called by muse, mutect2
- HEPH | c.106C>T p.Q36* (on ENST00000343002; = p.Q90* on NM_138737.5) | Nonsense Mutation (SNP) | VAF 106/498 reads (21%) | called by muse, mutect2, varscan2
- HERC5 | c.831T>G p.H277Q | Missense Mutation (SNP) | VAF 63/220 reads (29%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- HERC6 | c.1006T>A p.C336S | Missense Mutation (SNP) | VAF 7/110 reads (6%) | SIFT tolerated (0.3); PolyPhen benign (0.007); called by muse, mutect2
- HLA-DPB1 | c.56T>C p.L19P | Missense Mutation (SNP) | VAF 16/437 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- HMGXB4 | c.478C>T p.P160S | Missense Mutation (SNP) | VAF 28/193 reads (15%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- HOXD12 | c.340C>T p.R114C | Missense Mutation (SNP) | VAF 60/1112 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- HOXD3 | c.239C>T p.A80V | Missense Mutation (SNP) | VAF 118/431 reads (27%) | SIFT tolerated (0.43); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- HR | c.1341G>T p.Q447H | Missense Mutation (SNP) | VAF 24/154 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- HUNK | c.191G>A p.G64D | Missense Mutation (SNP) | VAF 58/528 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- HYDIN | c.11708A>C p.K3903T | Missense Mutation (SNP) | VAF 112/526 reads (21%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.52); called by muse, mutect2, varscan2
- IGF2BP2 | c.275A>G p.H92R | Missense Mutation (SNP) | VAF 31/274 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.223); called by muse, mutect2, varscan2
- IGSF1 | c.3859C>T p.P1287S | Missense Mutation (SNP) | VAF 36/284 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- IL18R1 | c.554G>A p.C185Y | Missense Mutation (SNP) | VAF 23/105 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- IL4 | c.457A>C p.S153R | Missense Mutation (SNP) | VAF 9/126 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); called by muse, mutect2
- INHBE | c.922del p.W308Gfs*57 | Frame Shift Del (DEL) | VAF 65/661 reads (10%) | called by mutect2, pindel, varscan2
- INTS11 | c.482C>T p.A161V | Missense Mutation (SNP) | VAF 53/498 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.738); called by muse, mutect2, varscan2
- ISG20 | c.441dup p.G148Wfs*89 | Frame Shift Ins (INS) | VAF 73/589 reads (12%) | called by mutect2, pindel, varscan2
- ITGA1 | c.3524del p.K1175Rfs*13 | Frame Shift Del (DEL) | VAF 12/59 reads (20%) | called by mutect2, pindel, varscan2
- JAK1 | c.2580del p.K860Nfs*16 | Frame Shift Del (DEL) | VAF 52/215 reads (24%) | called by mutect2, varscan2
- JAM3 | c.712+2T>C p.X238_splice | Splice Site (SNP) | VAF 173/669 reads (26%) | called by muse, mutect2, varscan2
- KAT5 | c.374T>A p.I125N | Missense Mutation (SNP) | VAF 107/652 reads (16%) | SIFT tolerated (0.4); PolyPhen benign (0.144); called by muse, mutect2, varscan2
- KCNH6 | c.422G>A p.S141N | Missense Mutation (SNP) | VAF 17/435 reads (4%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2
- KCNK15 | c.797del p.P266Rfs*99 | Frame Shift Del (DEL) | VAF 37/345 reads (11%) | called by mutect2, pindel, varscan2
- KCNK5 | c.607A>G p.T203A | Missense Mutation (SNP) | VAF 52/921 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); called by muse, mutect2
- KCNQ2 | c.1887+2T>C p.X629_splice (on ENST00000359125 / NM_172107.4; = p.X601_splice on NM_004518.6) | Splice Site (SNP) | VAF 56/527 reads (11%) | called by muse, varscan2
- KCNV1 | c.389C>T p.A130V | Missense Mutation (SNP) | VAF 46/606 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.031); called by muse, mutect2
- KHDRBS1 | c.1296G>T p.K432N | Missense Mutation (SNP) | VAF 48/398 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.351); called by muse, mutect2, varscan2
- KIAA2012 | c.2515A>T p.K839* | Nonsense Mutation (SNP) | VAF 20/144 reads (14%) | called by mutect2, varscan2
- KISS1R | c.311dup p.L105Afs*89 | Frame Shift Ins (INS) | VAF 245/1127 reads (22%) | called by mutect2, pindel, varscan2
- KLF11 | c.160A>T p.M54L | Missense Mutation (SNP) | VAF 151/627 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- KLK14 | c.682C>T p.P228S | Missense Mutation (SNP) | VAF 67/681 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- KMT2B | c.7934G>A p.G2645D | Missense Mutation (SNP) | VAF 52/656 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- KMT5B | c.101A>G p.H34R | Missense Mutation (SNP) | VAF 71/312 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- KY | c.1830G>T p.K610N | Missense Mutation (SNP) | VAF 14/164 reads (9%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.602); called by muse, mutect2
- LCMT2 | c.1356del p.F452Lfs*11 | Frame Shift Del (DEL) | VAF 73/328 reads (22%) | called by mutect2, pindel, varscan2
- LRP10 | c.1912C>A p.P638T | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.052); called by muse, mutect2
- LRRC18 | c.269A>G p.E90G | Missense Mutation (SNP) | VAF 81/412 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.419); called by muse, mutect2, varscan2
- LRRIQ3 | c.1077C>G p.Y359* | Nonsense Mutation (SNP) | VAF 22/86 reads (26%) | called by muse, mutect2, varscan2
- LYSMD2 | c.502C>A p.P168T | Missense Mutation (SNP) | VAF 43/424 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- MACC1 | c.100del p.S34Vfs*48 | Frame Shift Del (DEL) | VAF 20/151 reads (13%) | called by mutect2, pindel, varscan2
- MADCAM1 | c.482C>T p.A161V | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- MAGEB3 | c.980G>A p.G327D | Missense Mutation (SNP) | VAF 16/174 reads (9%) | SIFT tolerated (0.52); PolyPhen benign (0.007); called by muse, mutect2
- MAP1B | c.971T>A p.L324* | Nonsense Mutation (SNP) | VAF 45/442 reads (10%) | called by muse, mutect2, varscan2
- MAP3K1 | c.2286_2289del p.R763Cfs*35 | Frame Shift Del (DEL) | VAF 35/275 reads (13%) | called by pindel, varscan2
- MAP3K10 | c.2203G>T p.G735C | Missense Mutation (SNP) | VAF 17/333 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.054); called by muse, mutect2
- MAP3K14 | c.952C>A p.L318M | Missense Mutation (SNP) | VAF 60/616 reads (10%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.259); called by muse, mutect2
- MARK2 | c.1687del p.Q563Sfs*53 (on ENST00000402010 / NM_001039469.2; = p.Q508Sfs*53 on NM_004954.5) | Frame Shift Del (DEL) | VAF 53/250 reads (21%) | called by mutect2, pindel
- MAST2 | c.2345A>G p.H782R | Missense Mutation (SNP) | VAF 72/285 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.678); called by muse, mutect2, varscan2
- MCM3AP | c.776del p.L259Wfs*29 | Frame Shift Del (DEL) | VAF 40/340 reads (12%) | called by mutect2, varscan2
- MCRIP2 | c.325C>A p.Q109K | Missense Mutation (SNP) | VAF 122/1103 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- MEGF8 | c.5155G>C p.A1719P (on ENST00000251268 / NM_001271938.2; = p.A1652P on NM_001410.3) | Missense Mutation (SNP) | VAF 49/497 reads (10%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- MFAP3L | c.322G>T p.G108C | Missense Mutation (SNP) | VAF 19/129 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MFSD2A | c.268G>A p.V90M (on ENST00000372809 / NM_001136493.3; = p.V77M on NM_032793.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 111/441 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- MFSD5 | c.235A>G p.I79V | Missense Mutation (SNP) | VAF 109/424 reads (26%) | SIFT tolerated (0.36); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- MGAM | c.5453G>A p.G1818D | Missense Mutation (SNP) | VAF 27/132 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- MGAT5B | c.75del p.F25Lfs*13 | Frame Shift Del (DEL) | VAF 211/911 reads (23%) | called by mutect2, pindel, varscan2
- MIER3 | c.760C>A p.L254I | Missense Mutation (SNP) | VAF 10/196 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- MINDY4B | c.368del p.K123Rfs*13 | Frame Shift Del (DEL) | VAF 32/143 reads (22%) | called by mutect2, pindel, varscan2
- MOCS1 | c.1707C>G p.D569E | Missense Mutation (SNP) | VAF 185/606 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- MRPL28 | c.219del p.E74Nfs*28 | Frame Shift Del (DEL) | VAF 62/464 reads (13%) | called by mutect2, pindel, varscan2
- MSRA | c.628C>T p.Q210* | Nonsense Mutation (SNP) | VAF 27/482 reads (6%) | called by muse, mutect2
- MUC5B | c.16753del p.E5585Sfs*17 | Frame Shift Del (DEL) | VAF 61/582 reads (10%) | called by mutect2, pindel, varscan2
- MUSK | c.908T>C p.I303T | Missense Mutation (SNP) | VAF 7/103 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.118); called by muse, mutect2
- MYBPC1 | c.41C>T p.A14V | Missense Mutation (SNP) | VAF 86/599 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- NAV3 | c.3045A>C p.K1015N | Missense Mutation (SNP) | VAF 7/92 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- NCKAP5 | c.3104G>T p.G1035V | Missense Mutation (SNP) | VAF 14/114 reads (12%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.822); called by muse, mutect2, varscan2
- NCR1 | c.422C>T p.T141I | Missense Mutation (SNP) | VAF 34/390 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.888); called by muse, mutect2
- NES | c.80del p.K27Rfs*83 | Frame Shift Del (DEL) | VAF 322/1882 reads (17%) | called by pindel, varscan2
- NFATC3 | c.86del p.P29Rfs*21 | Frame Shift Del (DEL) | VAF 81/446 reads (18%) | called by pindel, varscan2
- NLRP8 | c.1497G>T p.E499D | Missense Mutation (SNP) | VAF 11/244 reads (5%) | SIFT tolerated (0.64); PolyPhen benign (0.005); called by muse, mutect2
- NOTCH2 | c.4160del p.G1387Afs*40 | Frame Shift Del (DEL) | VAF 22/226 reads (10%) | called by mutect2, pindel
- NPM3 | c.324G>A p.M108I | Missense Mutation (SNP) | VAF 31/258 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.294); called by muse, mutect2, varscan2
- NRIP1 | c.923G>A p.G308D | Missense Mutation (SNP) | VAF 43/179 reads (24%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.787); called by muse, mutect2, varscan2
- NUDT22 | c.410T>C p.L137P | Missense Mutation (SNP) | VAF 112/403 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- NUMA1 | c.1279G>A p.A427T | Missense Mutation (SNP) | VAF 34/143 reads (24%) | SIFT tolerated (0.51); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- NUP58 | c.118G>A p.V40M | Missense Mutation (SNP) | VAF 28/180 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.222); called by muse, mutect2, varscan2
- OBSCN | c.6722A>G p.D2241G | Missense Mutation (SNP) | VAF 62/885 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.356); called by muse, mutect2
- OBSCN | c.18163C>A p.Q6055K | Missense Mutation (SNP) | VAF 32/356 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.024); called by muse, mutect2
- OGG1 | c.743C>T p.T248I | Missense Mutation (SNP) | VAF 85/646 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- OR1S2 | c.922A>G p.K308E | Missense Mutation (SNP) | VAF 41/159 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- OR7C2 | c.899T>C p.L300P | Missense Mutation (SNP) | VAF 30/263 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PABPC1L | c.1489A>C p.S497R | Missense Mutation (SNP) | VAF 38/540 reads (7%) | SIFT tolerated (0.82); PolyPhen benign (0.003); called by muse, mutect2
- PABPC5 | c.191T>C p.V64A | Missense Mutation (SNP) | VAF 117/423 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PAN3 | c.68C>T p.A23V | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PAPLN | c.2938A>G p.S980G (on ENST00000554301; = p.S953G on NM_173462.4) | Missense Mutation (SNP) | VAF 41/594 reads (7%) | SIFT tolerated (0.3); PolyPhen benign (0.011); called by muse, mutect2
- PAPPA2 | c.4785T>A p.C1595* | Nonsense Mutation (SNP) | VAF 68/896 reads (8%) | called by muse, mutect2
- PER2 | c.613C>A p.L205M | Missense Mutation (SNP) | VAF 163/645 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.41); called by muse, mutect2, varscan2
- PIGR | c.235G>A p.A79T | Missense Mutation (SNP) | VAF 21/700 reads (3%) | SIFT tolerated (0.58); PolyPhen benign (0.01); called by muse, mutect2
- PKDCC | c.1035G>T p.R345S | Missense Mutation (SNP) | VAF 32/221 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- PLAU | c.931A>G p.T311A | Missense Mutation (SNP) | VAF 54/540 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.003); called by muse, mutect2
- PLXNB2 | c.3365C>A p.A1122E | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- PLXNB3 | c.3095T>C p.L1032P | Missense Mutation (SNP) | VAF 14/214 reads (7%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.707); called by muse, mutect2
- POLB | c.504del p.V169Wfs*27 | Frame Shift Del (DEL) | VAF 18/114 reads (16%) | called by mutect2, pindel, varscan2
- PPP1R16B | c.1029-2A>G p.X343_splice | Splice Site (SNP) | VAF 22/372 reads (6%) | called by muse, mutect2
- PRRT4 | c.2656C>T p.Q886* | Nonsense Mutation (SNP) | VAF 34/808 reads (4%) | called by muse, mutect2
- PRSS21 | c.8C>T p.A3V | Missense Mutation (SNP) | VAF 71/592 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- PRUNE1 | c.137C>T p.T46I | Missense Mutation (SNP) | VAF 14/168 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.038); called by muse, mutect2
- PSME1 | c.406C>T p.Q136* | Nonsense Mutation (SNP) | VAF 13/323 reads (4%) | called by muse, mutect2
- PTCHD4 | c.2429del p.F810Sfs*25 | Frame Shift Del (DEL) | VAF 14/124 reads (11%) | called by mutect2, pindel, varscan2
- PTTG1 | c.522G>T p.W174C | Missense Mutation (SNP) | VAF 77/312 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- PXMP4 | c.371G>A p.S124N | Missense Mutation (SNP) | VAF 49/198 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- QPCT | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 31/726 reads (4%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.099); called by muse, mutect2
- RASGEF1C | c.661C>T p.P221S | Missense Mutation (SNP) | VAF 26/432 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- RBBP6 | c.3933_3935del p.I1312del | In Frame Del (DEL) | VAF 9/74 reads (12%) | called by mutect2, pindel, varscan2
- RBM23 | c.565G>A p.V189I (on ENST00000359890 / NM_001077351.2; = p.V173I on NM_018107.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 37/306 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- RBM6 | c.3353G>T p.R1118L | Missense Mutation (SNP) | VAF 36/155 reads (23%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.995); called by muse, mutect2
- RCC2 | c.464C>T p.S155L | Missense Mutation (SNP) | VAF 33/419 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.119); called by muse, mutect2
- RCOR1 | c.151G>T p.A51S | Missense Mutation (SNP) | VAF 103/299 reads (34%) | SIFT tolerated, low confidence (0.25); called by muse, mutect2, varscan2
- RFPL4B | c.347G>A p.S116N | Missense Mutation (SNP) | VAF 70/629 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- RFX6 | c.1506dup p.G503Wfs*7 | Frame Shift Ins (INS) | VAF 28/234 reads (12%) | called by mutect2, varscan2
- RGS7BP | c.692G>A p.S231N | Missense Mutation (SNP) | VAF 48/337 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- RIF1 | c.745G>C p.V249L | Missense Mutation (SNP) | VAF 40/198 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- RLBP1 | c.499C>T p.Q167* | Nonsense Mutation (SNP) | VAF 22/522 reads (4%) | called by muse, mutect2
- RNF10 | c.2260G>A p.D754N | Missense Mutation (SNP) | VAF 136/546 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- RNF113B | c.812G>A p.C271Y | Missense Mutation (SNP) | VAF 19/651 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- RPL11 | c.380T>C p.L127P (on ENST00000374550 / NM_001199802.1; = p.L128P on NM_000975.5) | Missense Mutation (SNP) | VAF 65/549 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- RRAGA | c.122C>G p.A41G | Missense Mutation (SNP) | VAF 32/611 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.45); called by muse, mutect2
- SCAF1 | c.977C>A p.P326H | Missense Mutation (SNP) | VAF 33/304 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.785); called by muse, mutect2, varscan2
- SCAF8 | c.2575C>T p.P859S | Missense Mutation (SNP) | VAF 20/189 reads (11%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.702); called by muse, mutect2, varscan2
- SCMH1 | c.1713A>G p.P571= | Splice Region (SNP) | VAF 24/183 reads (13%) | called by muse, mutect2, varscan2
- SCN2A | c.71C>T p.A24V | Missense Mutation (SNP) | VAF 147/572 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SCUBE1 | c.2747A>G p.Q916R | Missense Mutation (SNP) | VAF 96/690 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.655); called by muse, mutect2, varscan2
- SEMG1 | c.1298dup p.L434Ifs*11 | Frame Shift Ins (INS) | VAF 47/194 reads (24%) | called by mutect2, pindel, varscan2
- SERINC4 | c.1552G>A p.V518I | Missense Mutation (SNP) | VAF 19/124 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- SERINC5 | c.736G>A p.V246I | Missense Mutation (SNP) | VAF 46/346 reads (13%) | SIFT tolerated (0.4); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SERPINA6 | c.1115C>A p.S372Y | Missense Mutation (SNP) | VAF 171/622 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- SERPINB13 | c.1039G>A p.A347T | Missense Mutation (SNP) | VAF 41/472 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- SETD1B | c.22del p.H8Tfs*27 | Frame Shift Del (DEL) | VAF 37/129 reads (29%) | called by mutect2, varscan2
- SETD2 | c.5026dup p.Q1676Pfs*36 | Frame Shift Ins (INS) | VAF 24/221 reads (11%) | called by mutect2, pindel, varscan2
- SETD3 | c.1546dup p.D516Gfs*41 | Frame Shift Ins (INS) | VAF 44/470 reads (9%) | called by mutect2, pindel
- SETD4 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 10/117 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.201); called by muse, mutect2
- SHANK2 | c.4568G>A p.G1523D | Missense Mutation (SNP) | VAF 133/1018 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SHANK3 | c.510G>T p.K170N | Missense Mutation (SNP) | VAF 96/419 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- SHFL | c.565_566del p.P189Afs*57 | Frame Shift Del (DEL) | VAF 38/336 reads (11%) | called by pindel, varscan2
- SIK2 | c.2072C>T p.S691L | Missense Mutation (SNP) | VAF 10/232 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.033); called by muse, mutect2
- SKOR1 | c.2323G>T p.A775S | Missense Mutation (SNP) | VAF 13/425 reads (3%) | SIFT tolerated (0.21); PolyPhen benign (0.027); called by muse, mutect2
- SLC13A5 | c.622A>G p.M208V | Missense Mutation (SNP) | VAF 21/680 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.285); called by muse, mutect2
- SLC47A1 | c.237G>T p.A79= | Splice Region (SNP) | VAF 34/148 reads (23%) | called by muse, mutect2, varscan2
- SLC4A11 | c.1630C>A p.L544I | Missense Mutation (SNP) | VAF 68/1478 reads (5%) | SIFT tolerated (0.32); PolyPhen benign (0.029); called by muse, mutect2
- SLC7A10 | c.1541C>T p.P514L | Missense Mutation (SNP) | VAF 69/655 reads (11%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- SMCHD1 | c.5115del p.K1705Nfs*25 | Frame Shift Del (DEL) | VAF 7/66 reads (11%) | called by mutect2, pindel, varscan2
- SMCR8 | c.2485dup p.R829Pfs*69 | Frame Shift Ins (INS) | VAF 193/944 reads (20%) | called by mutect2, pindel, varscan2
- SND1 | c.2168del p.P723Lfs*2 | Frame Shift Del (DEL) | VAF 28/122 reads (23%) | called by mutect2, pindel, varscan2
- SOX18 | c.539del p.P180Rfs*186 | Frame Shift Del (DEL) | VAF 45/423 reads (11%) | called by mutect2, pindel, varscan2
- SOX6 | c.992C>A p.S331Y | Missense Mutation (SNP) | VAF 56/506 reads (11%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0.021); called by muse, varscan2
- SPCS3 | c.149dup p.N50Kfs*9 | Frame Shift Ins (INS) | VAF 9/68 reads (13%) | called by mutect2, pindel
- SPEF2 | c.4218-2A>G p.X1406_splice | Splice Site (SNP) | VAF 6/60 reads (10%) | called by muse, mutect2, varscan2
- SSTR1 | c.1108C>T p.P370S | Missense Mutation (SNP) | VAF 35/258 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- SSTR4 | c.50C>T p.T17M | Missense Mutation (SNP) | VAF 33/318 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.438); called by muse, mutect2, varscan2
- SUN3 | c.42del p.F14Lfs*29 | Frame Shift Del (DEL) | VAF 40/334 reads (12%) | called by mutect2, pindel, varscan2
- SUPT5H | c.2725del p.Q909Rfs*45 | Frame Shift Del (DEL) | VAF 43/278 reads (15%) | called by mutect2, pindel, varscan2
- TACC3 | c.2452-2A>G p.X818_splice | Splice Site (SNP) | VAF 14/376 reads (4%) | called by muse, mutect2
- TAF1L | c.2553del p.A852Pfs*14 | Frame Shift Del (DEL) | VAF 147/662 reads (22%) | called by mutect2, pindel, varscan2
- TANGO2 | c.683G>A p.C228Y | Missense Mutation (SNP) | VAF 81/306 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.228); called by muse, mutect2, varscan2
- TARDBP | c.742T>G p.L248V | Missense Mutation (SNP) | VAF 64/262 reads (24%) | SIFT tolerated (0.53); PolyPhen benign (0.131); called by muse, mutect2, varscan2
- TASOR2 | c.3095A>T p.H1032L | Missense Mutation (SNP) | VAF 32/230 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- TBX15 | c.89G>A p.R30Q | Missense Mutation (SNP) | VAF 36/1040 reads (3%) | SIFT tolerated (0.16); PolyPhen benign (0.043); called by muse, mutect2
- TLE1 | c.1699A>G p.K567E | Missense Mutation (SNP) | VAF 119/872 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TLR9 | c.1407C>A p.N469K | Missense Mutation (SNP) | VAF 11/124 reads (9%) | SIFT tolerated (0.72); PolyPhen benign (0.025); called by muse, mutect2
- TMEM164 | c.368G>A p.C123Y | Missense Mutation (SNP) | VAF 24/131 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TMEM185B | c.866del p.L289* | Frame Shift Del (DEL) | VAF 21/167 reads (13%) | called by mutect2, pindel, varscan2
- TMEM260 | c.1678A>G p.I560V | Missense Mutation (SNP) | VAF 60/230 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TMEM87A | c.1369A>G p.M457V | Missense Mutation (SNP) | VAF 82/326 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- TNPO3 | c.1763A>G p.Q588R | Missense Mutation (SNP) | VAF 7/128 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.214); called by muse, mutect2
- TRAJ47 | c.13A>T p.N5Y | Missense Mutation (SNP) | VAF 19/298 reads (6%) | called by muse, mutect2
- TRIM72 | c.89G>A p.G30D | Missense Mutation (SNP) | VAF 78/1168 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TRPC6 | c.1334C>T p.A445V | Missense Mutation (SNP) | VAF 71/532 reads (13%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TSPAN15 | c.839G>A p.S280N | Missense Mutation (SNP) | VAF 90/982 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.006); called by muse, mutect2
- TSPOAP1 | c.1653del p.C552Afs*80 | Frame Shift Del (DEL) | VAF 40/167 reads (24%) | called by mutect2, pindel
- TTI2 | c.349G>A p.G117R | Missense Mutation (SNP) | VAF 79/766 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.726); called by muse, mutect2, varscan2
- TTLL5 | c.3121G>A p.A1041T | Missense Mutation (SNP) | VAF 13/128 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- UGT2B7 | c.1543del p.C515Vfs*19 | Frame Shift Del (DEL) | VAF 91/418 reads (22%) | called by mutect2, pindel, varscan2
- UNC45B | c.2284G>A p.A762T | Missense Mutation (SNP) | VAF 20/286 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); called by muse, mutect2
- UQCC3 | c.161C>T p.A54V | Missense Mutation (SNP) | VAF 155/581 reads (27%) | SIFT tolerated (0.34); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- URB1 | c.3965A>G p.Y1322C | Missense Mutation (SNP) | VAF 36/380 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.346); called by muse, mutect2
- UROC1 | c.1126A>G p.K376E | Missense Mutation (SNP) | VAF 66/747 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.595); called by muse, mutect2
- USP17L2 | c.398C>T p.T133I | Missense Mutation (SNP) | VAF 142/2731 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.27); called by muse, mutect2
- USP51 | c.581dup p.C195Lfs*8 | Frame Shift Ins (INS) | VAF 32/316 reads (10%) | called by mutect2, pindel, varscan2
- USPL1 | c.2460T>A p.S820R | Missense Mutation (SNP) | VAF 18/137 reads (13%) | SIFT tolerated (0.35); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- VCPIP1 | c.910_912del p.I304del | In Frame Del (DEL) | VAF 35/131 reads (27%) | called by pindel, varscan2
- VIT | c.1994T>C p.I665T (on ENST00000389975 / NM_001177969.1; = p.I680T on NM_053276.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/288 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); called by muse, mutect2, varscan2
- VPS16 | c.230C>T p.A77V | Missense Mutation (SNP) | VAF 24/326 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.265); called by muse, mutect2
- VSX2 | c.208C>A p.P70T | Missense Mutation (SNP) | VAF 26/511 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.637); called by muse, mutect2
- VTI1A | c.472G>T p.E158* | Nonsense Mutation (SNP) | VAF 10/236 reads (4%) | called by muse, mutect2
- VWA2 | c.1938G>T p.E646D | Missense Mutation (SNP) | VAF 78/856 reads (9%) | SIFT tolerated (0.3); PolyPhen benign (0.07); called by muse, mutect2
- WHAMM | c.814A>G p.R272G | Missense Mutation (SNP) | VAF 41/149 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.167); called by muse, mutect2, varscan2
- XKR4 | c.692G>A p.S231N | Missense Mutation (SNP) | VAF 54/587 reads (9%) | SIFT tolerated (0.33); PolyPhen benign (0.001); called by muse, mutect2
- YTHDF3 | c.411del p.T138Qfs*41 | Frame Shift Del (DEL) | VAF 26/220 reads (12%) | called by mutect2, pindel, varscan2
- ZBTB18 | c.1147del p.H383Tfs*7 | Frame Shift Del (DEL) | VAF 28/282 reads (10%) | called by mutect2, pindel
- ZFAT | c.2281G>A p.V761I | Missense Mutation (SNP) | VAF 10/125 reads (8%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.833); called by muse, mutect2
- ZFPM1 | c.1582C>T p.Q528* | Nonsense Mutation (SNP) | VAF 138/476 reads (29%) | called by muse, mutect2, varscan2
- ZMYM2 | c.3749del p.N1250Ifs*3 | Frame Shift Del (DEL) | VAF 48/191 reads (25%) | called by mutect2, varscan2
- ZNF33B | c.970A>G p.K324E | Missense Mutation (SNP) | VAF 16/270 reads (6%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.98); called by muse, mutect2
- ZNF345 | c.362A>G p.K121R | Missense Mutation (SNP) | VAF 14/195 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.015); called by muse, mutect2
- ZNF367 | c.28G>A p.A10T | Missense Mutation (SNP) | VAF 37/132 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.115); called by muse, mutect2
- ZNF423 | c.2611C>A p.L871I (on ENST00000563137 / NM_001379286.1; = p.L863I on NM_015069.4) | Missense Mutation (SNP) | VAF 119/417 reads (29%) | SIFT tolerated (0.47); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- ZNF462 | c.901A>G p.T301A | Missense Mutation (SNP) | VAF 21/438 reads (5%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.015); called by muse, mutect2
- ABCA1 | c.3765T>C p.S1255= | Silent (SNP) | VAF 36/735 reads (5%) | catalogued as rs1219212446; called by muse, mutect2
- ABCA7 | c.3045C>T p.R1015= | Silent (SNP) | VAF 30/929 reads (3%) | called by muse, mutect2
- ABCB7 | c.867C>T p.C289= (on ENST00000373394 / NM_001271696.3; = p.C290= on NM_004299.6) | Silent (SNP) | VAF 66/460 reads (14%) | catalogued as rs769487666, COSV53719399; called by muse, mutect2, varscan2
- ACLY | c.1782C>T p.I594= | Silent (SNP) | VAF 16/462 reads (3%) | catalogued as rs1555628518, COSV100709636; called by muse, mutect2
- ACTR1B | c.792G>A p.Q264= | Silent (SNP) | VAF 108/331 reads (33%) | called by muse, mutect2, varscan2
- ACTRT1 | c.396G>A p.V132= | Silent (SNP) | VAF 72/245 reads (29%) | called by muse, mutect2, varscan2
- ADAD2 | c.285G>A p.P95= | Silent (SNP) | VAF 65/479 reads (14%) | catalogued as rs577200150; called by muse, mutect2, varscan2
- ADAMTS10 | c.3003C>T p.R1001= | Silent (SNP) | VAF 9/105 reads (9%) | called by muse, mutect2
- ADGRF1 | c.2398C>T p.L800= | Silent (SNP) | VAF 18/192 reads (9%) | called by muse, mutect2
- ADRA2A | c.948C>T p.H316= | Silent (SNP) | VAF 37/151 reads (25%) | called by muse, mutect2, varscan2
- AFDN | c.2667T>C p.P889= | Silent (SNP) | VAF 17/44 reads (39%) | catalogued as rs1200017389; called by muse, mutect2, varscan2
- AKAP3 | c.138C>A p.R46= | Silent (SNP) | VAF 34/109 reads (31%) | called by muse, mutect2, varscan2
- ALMS1 | c.11643C>T p.H3881= | Silent (SNP) | VAF 68/249 reads (27%) | called by muse, mutect2, varscan2
- ALS2 | c.4465C>T p.L1489= | Silent (SNP) | VAF 92/350 reads (26%) | called by muse, mutect2, varscan2
- ANHX | c.495T>C p.A165= | Silent (SNP) | VAF 22/352 reads (6%) | called by muse, mutect2
- ANO4 | c.1077C>T p.G359= (on ENST00000392977 / NM_001286615.2; = p.G324= on NM_178826.4) | Silent (SNP) | VAF 66/342 reads (19%) | called by muse, mutect2, varscan2
- APMAP | c.831C>T p.T277= | Silent (SNP) | VAF 15/78 reads (19%) | called by muse, mutect2, varscan2
- AR | c.1332C>T p.G444= | Silent (SNP) | VAF 48/469 reads (10%) | called by muse, mutect2, varscan2
- ARID4B | c.3906A>G p.A1302= | Silent (SNP) | VAF 15/353 reads (4%) | called by muse, mutect2
- ARMCX5 | c.438T>C p.T146= | Silent (SNP) | VAF 16/338 reads (5%) | called by muse, mutect2
- ARMH4 | c.2301C>T p.A767= | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as rs767995153; called by muse, mutect2, varscan2
- ATAD5 | c.4371C>T p.G1457= | Silent (SNP) | VAF 25/128 reads (20%) | called by muse, mutect2, varscan2
- ATMIN | c.1029A>G p.L343= | Silent (SNP) | VAF 35/230 reads (15%) | called by muse, mutect2, varscan2
- ATP8A1 | c.1503T>C p.Y501= | Silent (SNP) | VAF 38/323 reads (12%) | catalogued as COSV100045308; called by muse, mutect2, varscan2
- AURKC | c.909C>A p.P303= (on ENST00000302804 / NM_001015878.2; = p.P269= on NM_003160.3) | Silent (SNP) | VAF 66/740 reads (9%) | called by muse, mutect2
- B3GNT9 | c.282G>A p.R94= | Silent (SNP) | VAF 31/262 reads (12%) | called by muse, mutect2, varscan2
- BCORL1 | c.2781C>T p.S927= | Silent (SNP) | VAF 44/412 reads (11%) | called by muse, mutect2
- BDKRB2 | c.829C>T p.L277= | Silent (SNP) | VAF 12/74 reads (16%) | called by muse, mutect2, varscan2
- BEND3 | c.1041C>T p.D347= | Silent (SNP) | VAF 20/694 reads (3%) | catalogued as rs987719261; called by muse, mutect2
- BICRA | c.774C>T p.P258= | Silent (SNP) | VAF 14/256 reads (5%) | catalogued as rs1274412015; called by muse, mutect2
- BPI | c.162C>T p.A54= (on ENST00000262865; = p.A50= on NM_001725.3) | Silent (SNP) | VAF 37/123 reads (30%) | catalogued as rs770427994, COSV53405829; called by muse, mutect2, varscan2
- C5orf22 | c.1134T>C p.C378= | Silent (SNP) | VAF 20/191 reads (10%) | catalogued as rs541364888; called by muse, mutect2, varscan2
- CA1 | c.192G>T p.G64= | Silent (SNP) | VAF 50/345 reads (14%) | called by muse, mutect2, varscan2
- CBLN4 | c.144G>A p.P48= | Silent (SNP) | VAF 191/789 reads (24%) | catalogued as COSV99290753; called by muse, mutect2, varscan2
- CBX5 | c.291T>C p.S97= | Silent (SNP) | VAF 51/185 reads (28%) | called by muse, mutect2, varscan2
- CCDC61 | c.435C>T p.P145= | Silent (SNP) | VAF 84/345 reads (24%) | catalogued as rs748456843; called by muse, mutect2, varscan2
- CDCP2 | c.147G>A p.L49= | Silent (SNP) | VAF 100/396 reads (25%) | called by muse, mutect2, varscan2
- CDH6 | c.1827G>A p.T609= | Silent (SNP) | VAF 34/534 reads (6%) | catalogued as rs145080455, COSV99418323; called by muse, mutect2
- CEACAM6 | c.804G>A p.Q268= | Silent (SNP) | VAF 26/635 reads (4%) | catalogued as rs1386097010; called by muse, mutect2
- CENPF | c.1932T>C p.I644= | Silent (SNP) | VAF 28/418 reads (7%) | called by muse, mutect2
- CES4A | c.504G>A p.L168= | Silent (SNP) | VAF 29/968 reads (3%) | called by muse, mutect2
- CHD3 | c.5446C>T p.L1816= (on ENST00000330494 / NM_001005273.3; = p.L1782= on NM_005852.4) | Silent (SNP) | VAF 32/1260 reads (3%) | called by muse, mutect2
- CHTF18 | c.663G>A p.V221= | Silent (SNP) | VAF 126/1080 reads (12%) | called by muse, mutect2, varscan2
- CLCA4 | c.2697G>A p.T899= | Silent (SNP) | VAF 12/84 reads (14%) | catalogued as rs369434811, COSV65284030; called by muse, mutect2
- CLCN4 | c.975G>A p.T325= | Silent (SNP) | VAF 40/374 reads (11%) | catalogued as rs73483205, COSV101073693; called by muse, mutect2, varscan2
- CLK4 | c.1392T>C p.I464= | Silent (SNP) | VAF 9/63 reads (14%) | called by muse, mutect2, varscan2
- CNTN2 | c.3081C>T p.H1027= | Silent (SNP) | VAF 141/804 reads (18%) | catalogued as rs749856453; called by muse, mutect2, varscan2
- CNTNAP2 | c.429C>T p.D143= | Silent (SNP) | VAF 131/519 reads (25%) | catalogued as rs866657669; called by muse, mutect2, varscan2
- COL18A1 | c.2736T>C p.G912= (on ENST00000359759 / NM_130444.3; = p.G677= on NM_030582.4) | Silent (SNP) | VAF 159/1148 reads (14%) | called by muse, mutect2, varscan2
- CORO2B | c.315G>A p.S105= | Silent (SNP) | VAF 109/389 reads (28%) | catalogued as rs773156286, COSV55951377; called by muse, varscan2
- COX17 | c.177A>G p.L59= | Silent (SNP) | VAF 18/212 reads (8%) | catalogued as rs761746207; called by muse, mutect2
- CT55 | c.48C>T p.A16= | Silent (SNP) | VAF 119/539 reads (22%) | catalogued as rs782780501, COSV52277358; called by muse, mutect2, varscan2
- DCDC1 | c.1308G>A p.Q436= | Silent (SNP) | VAF 47/148 reads (32%) | called by muse, mutect2, varscan2
- DDX50 | c.1164T>C p.S388= | Silent (SNP) | VAF 38/442 reads (9%) | called by muse, mutect2
- DDX51 | c.1698G>A p.A566= | Silent (SNP) | VAF 71/343 reads (21%) | catalogued as rs550340511, COSV57957399; called by muse, mutect2, varscan2
- DEDD2 | c.660G>A p.R220= | Silent (SNP) | VAF 70/544 reads (13%) | catalogued as rs778327446; called by muse, mutect2, varscan2
- DERPC | c.114G>A p.L38= | Silent (SNP) | VAF 31/415 reads (7%) | catalogued as COSV54707947; called by muse, mutect2
- DNAH8 | c.3090C>A p.P1030= | Silent (SNP) | VAF 12/102 reads (12%) | called by muse, mutect2, varscan2
- DNAJC21 | c.822G>A p.R274= | Silent (SNP) | VAF 20/284 reads (7%) | called by muse, mutect2
- DST | c.8457C>T p.S2819= | Silent (SNP) | VAF 26/296 reads (9%) | catalogued as rs568559747, COSV55034638; called by muse, mutect2
- DYNC1H1 | c.13059C>T p.D4353= | Silent (SNP) | VAF 59/1089 reads (5%) | catalogued as rs773232010; ClinVar: likely benign; called by muse, mutect2
- EFCAB8 | c.2478C>T p.D826= | Silent (SNP) | VAF 164/690 reads (24%) | catalogued as rs1045640031; called by muse, mutect2, varscan2
- ELL | c.585C>T p.A195= | Silent (SNP) | VAF 82/747 reads (11%) | catalogued as rs772428991, COSV53216248; called by muse, mutect2, varscan2
- EML6 | c.3096T>A p.R1032= | Silent (SNP) | VAF 67/239 reads (28%) | called by muse, mutect2, varscan2
- EPB41L4A | c.1146A>G p.T382= | Silent (SNP) | VAF 12/192 reads (6%) | called by muse, mutect2
- EXO1 | c.2100T>C p.S700= | Silent (SNP) | VAF 15/171 reads (9%) | called by muse, mutect2
- EXT1 | c.2149C>T p.L717= | Silent (SNP) | VAF 18/414 reads (4%) | called by muse, mutect2
- F2RL3 | c.274C>T p.L92= | Silent (SNP) | VAF 35/801 reads (4%) | called by muse, mutect2
- FAM124A | c.1593A>G p.P531= (on ENST00000322475 / NM_001242312.2; = p.P567= on NM_145019.4) | Silent (SNP) | VAF 8/140 reads (6%) | called by muse, mutect2
- FAM81A | c.585G>A p.E195= | Silent (SNP) | VAF 50/245 reads (20%) | called by muse, mutect2, varscan2
- FAT3 | c.732T>C p.N244= | Silent (SNP) | VAF 21/185 reads (11%) | catalogued as rs748081064; called by muse, mutect2, varscan2
- FAT3 | c.8850C>T p.D2950= | Silent (SNP) | VAF 11/192 reads (6%) | called by muse, mutect2
- FAT4 | c.819G>A p.A273= | Silent (SNP) | VAF 8/68 reads (12%) | catalogued as rs748050828, COSV67890420; called by muse, mutect2, varscan2
- FBL | c.510G>A p.S170= | Silent (SNP) | VAF 34/252 reads (13%) | catalogued as rs1403528330; called by muse, mutect2, varscan2
- FBN1 | c.5871G>A p.Q1957= | Silent (SNP) | VAF 196/716 reads (27%) | catalogued as rs1203749556; called by muse, mutect2, varscan2
- FBXO46 | c.1359G>A p.S453= | Silent (SNP) | VAF 42/640 reads (7%) | catalogued as rs192506598; called by muse, mutect2
- FGF22 | c.303C>T p.G101= | Silent (SNP) | VAF 96/782 reads (12%) | catalogued as rs891901692; called by muse, mutect2, varscan2
- FHAD1 | c.1896C>T p.S632= | Silent (SNP) | VAF 155/594 reads (26%) | called by muse, mutect2, varscan2
- FRAS1 | c.8343C>T p.R2781= | Silent (SNP) | VAF 11/138 reads (8%) | called by muse, mutect2
- FRMD4A | c.2742C>A p.A914= | Silent (SNP) | VAF 8/155 reads (5%) | called by muse, mutect2
- FSTL4 | c.1377C>T p.D459= | Silent (SNP) | VAF 133/507 reads (26%) | catalogued as rs767927742, COSV54786391; called by muse, mutect2, varscan2
- FZD9 | c.915G>A p.Q305= | Silent (SNP) | VAF 130/484 reads (27%) | called by muse, mutect2, varscan2
- GAK | c.1011C>A p.G337= | Silent (SNP) | VAF 65/532 reads (12%) | called by muse, mutect2, varscan2
- GIT1 | c.943C>T p.L315= | Silent (SNP) | VAF 38/402 reads (9%) | called by muse, mutect2, varscan2
- GPR34 | c.441C>T p.F147= | Silent (SNP) | VAF 14/89 reads (16%) | catalogued as COSV59364329, COSV59366775; called by muse, mutect2, varscan2
- GRIN3B | c.2457G>T p.A819= | Silent (SNP) | VAF 62/220 reads (28%) | called by muse, mutect2, varscan2
- HEXIM2 | c.459G>A p.P153= | Silent (SNP) | VAF 215/758 reads (28%) | called by muse, mutect2, varscan2
- HMCN1 | c.2940G>A p.L980= | Silent (SNP) | VAF 94/435 reads (22%) | called by muse, mutect2, varscan2
- HOXD12 | c.474C>T p.C158= | Silent (SNP) | VAF 20/686 reads (3%) | catalogued as COSV66832519; called by muse, mutect2
- HS3ST4 | c.174C>T p.S58= | Silent (SNP) | VAF 67/495 reads (14%) | called by muse, mutect2, varscan2
- HSPG2 | c.8244C>T p.C2748= | Silent (SNP) | VAF 76/757 reads (10%) | catalogued as rs377526585, COSV65968768; called by muse, mutect2
- IFT52 | c.873C>T p.F291= | Silent (SNP) | VAF 26/235 reads (11%) | catalogued as rs778437833, COSV65974394; called by muse, mutect2, varscan2
- IL16 | c.3492C>A p.S1164= (on ENST00000302987 / NM_172217.5; = p.S463= on NM_004513.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 90/597 reads (15%) | catalogued as COSV57156006; called by muse, mutect2, varscan2
- IL4R | c.1473C>T p.I491= | Silent (SNP) | VAF 63/448 reads (14%) | catalogued as rs754262117; called by muse, mutect2, varscan2
- INKA1 | c.372G>A p.R124= | Silent (SNP) | VAF 67/617 reads (11%) | catalogued as rs950767659; called by muse, mutect2, varscan2
- INSRR | c.1437C>T p.R479= | Silent (SNP) | VAF 48/714 reads (7%) | catalogued as rs751982024; called by muse, mutect2
- IQCF3 | c.237G>A p.R79= | Silent (SNP) | VAF 44/348 reads (13%) | catalogued as rs1024889277; called by muse, mutect2, varscan2
- IRX2 | c.99C>T p.S33= | Silent (SNP) | VAF 99/669 reads (15%) | catalogued as rs1350560068; called by muse, mutect2, varscan2
- ITPR3 | c.1680G>A p.L560= | Silent (SNP) | VAF 21/325 reads (6%) | called by muse, mutect2
- KIF3A | c.1710A>G p.E570= | Silent (SNP) | VAF 29/171 reads (17%) | catalogued as rs904348479; called by muse, mutect2, varscan2
- KLHL34 | c.78C>T p.G26= | Silent (SNP) | VAF 32/325 reads (10%) | called by muse, mutect2, varscan2
- KLHL35 | c.1356C>T p.G452= | Silent (SNP) | VAF 69/600 reads (12%) | catalogued as rs776009576; called by muse, mutect2, varscan2
- KPNA2 | c.267T>C p.N89= | Silent (SNP) | VAF 30/174 reads (17%) | called by muse, mutect2, varscan2
- LILRA4 | c.1027C>T p.L343= | Silent (SNP) | VAF 126/414 reads (30%) | called by muse, varscan2
- LRRC32 | c.453G>A p.L151= | Silent (SNP) | VAF 56/424 reads (13%) | catalogued as rs753804494; called by muse, mutect2, varscan2
- LRRC53 | c.852T>C p.S284= | Silent (SNP) | VAF 9/218 reads (4%) | called by muse, mutect2
- MAGEB6 | c.1131C>T p.A377= | Silent (SNP) | VAF 136/507 reads (27%) | catalogued as rs138180623, COSV66873161; called by muse, mutect2, varscan2
- MAGED1 | c.69C>T p.S23= | Silent (SNP) | VAF 61/208 reads (29%) | catalogued as rs1557364027; called by muse, mutect2, varscan2
- MAGEE1 | c.2388T>C p.H796= | Silent (SNP) | VAF 35/251 reads (14%) | called by muse, mutect2, varscan2
- MAP2K2 | c.993T>A p.P331= | Silent (SNP) | VAF 60/227 reads (26%) | called by muse, mutect2, varscan2
- MAP3K8 | c.1191C>T p.R397= | Silent (SNP) | VAF 75/727 reads (10%) | called by muse, mutect2, varscan2
- MAPKBP1 | c.3960G>A p.R1320= (on ENST00000456763 / NM_001128608.2; = p.R1314= on NM_014994.3) | Silent (SNP) | VAF 141/516 reads (27%) | called by muse, mutect2, varscan2
- MEGF10 | c.246T>C p.H82= | Silent (SNP) | VAF 23/190 reads (12%) | called by muse, mutect2, varscan2
- MEP1A | c.1326C>A p.S442= | Silent (SNP) | VAF 11/134 reads (8%) | called by muse, mutect2
- MET | c.348C>T p.I116= | Silent (SNP) | VAF 40/443 reads (9%) | catalogued as COSV100577554, COSV99041960; called by muse, mutect2
- MKNK1 | c.1209C>T p.H403= | Silent (SNP) | VAF 52/480 reads (11%) | catalogued as rs773196707; called by muse, mutect2, varscan2
- MLLT10 | c.2616C>T p.G872= (on ENST00000307729 / NM_001195626.3; = p.G888= on NM_004641.3) | Silent (SNP) | VAF 30/474 reads (6%) | catalogued as rs563909825, COSV56999077; called by muse, mutect2
- MMACHC | c.315C>T p.Y105= | Silent (SNP) | VAF 60/316 reads (19%) | catalogued as rs528744719, CM106301, COSV53114971; called by muse, mutect2, varscan2
- MMP1 | c.1107C>T p.G369= | Silent (SNP) | VAF 64/335 reads (19%) | called by muse, mutect2, varscan2
- MROH6 | c.759C>T p.G253= | Silent (SNP) | VAF 72/293 reads (25%) | called by muse, mutect2, varscan2
- MROH8 | c.918C>T p.F306= | Silent (SNP) | VAF 26/322 reads (8%) | called by muse, mutect2
- MYH13 | c.2586G>A p.R862= | Silent (SNP) | VAF 53/364 reads (15%) | catalogued as rs1026157968, COSV52834563; called by muse, mutect2, varscan2
- MYH7B | c.4218G>A p.Q1406= | Silent (SNP) | VAF 21/512 reads (4%) | catalogued as rs1297862018; called by muse, mutect2
- MYO18B | c.5139G>A p.Q1713= | Silent (SNP) | VAF 11/323 reads (3%) | called by muse, mutect2
- NABP2 | c.549G>A p.Q183= | Silent (SNP) | VAF 60/631 reads (10%) | catalogued as rs1169682117; called by muse, mutect2
- NAPRT | c.1602G>T p.A534= | Silent (SNP) | VAF 109/1107 reads (10%) | catalogued as COSV52789801; called by muse, mutect2
- NEXMIF | c.2286A>G p.E762= | Silent (SNP) | VAF 58/262 reads (22%) | called by muse, mutect2, varscan2
- NLGN4X | c.2289G>A p.T763= | Silent (SNP) | VAF 209/775 reads (27%) | catalogued as rs781005111; called by muse, mutect2, varscan2
- NOP2 | c.1026A>G p.S342= (on ENST00000322166 / NM_001258308.2; = p.S338= on NM_006170.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 74/617 reads (12%) | called by muse, mutect2, varscan2
- NR4A1 | c.174C>T p.D58= | Silent (SNP) | VAF 121/459 reads (26%) | catalogued as rs774267356, COSV54485973; called by muse, mutect2, varscan2
- NTRK3 | c.1179C>G p.G393= | Silent (SNP) | VAF 22/575 reads (4%) | called by muse, mutect2
- NXPE3 | c.1482C>T p.S494= | Silent (SNP) | VAF 41/221 reads (19%) | called by muse, mutect2, varscan2
- OSBPL5 | c.273C>T p.A91= | Silent (SNP) | VAF 12/175 reads (7%) | called by muse, mutect2
- OTOG | c.8655C>T p.F2885= | Silent (SNP) | VAF 223/952 reads (23%) | catalogued as rs1440187610; called by muse, mutect2, varscan2
- PADI1 | c.1704T>C p.I568= | Silent (SNP) | VAF 23/318 reads (7%) | called by muse, mutect2
- PANK4 | c.891C>T p.H297= | Silent (SNP) | VAF 52/324 reads (16%) | catalogued as COSV65867564; called by muse, mutect2, varscan2
- PCDHB10 | c.1590C>T p.R530= | Silent (SNP) | VAF 118/1041 reads (11%) | catalogued as rs1486591969, COSV53384595; called by muse, mutect2, varscan2
- PCDHB13 | c.804G>T p.T268= | Silent (SNP) | VAF 79/541 reads (15%) | catalogued as COSV53394937; called by muse, mutect2, varscan2
- PCDHGA12 | c.1338C>T p.N446= | Silent (SNP) | VAF 42/340 reads (12%) | catalogued as rs1428283489; called by muse, mutect2, varscan2
- PCLO | c.10560G>A p.T3520= | Silent (SNP) | VAF 31/198 reads (16%) | catalogued as rs766410805; called by muse, mutect2, varscan2
- PGLYRP2 | c.894C>T p.H298= | Silent (SNP) | VAF 105/438 reads (24%) | catalogued as rs1568341998; called by muse, mutect2, varscan2
- PHF21A | c.291A>G p.Q97= | Silent (SNP) | VAF 247/985 reads (25%) | catalogued as rs151038480; called by muse, mutect2, varscan2
- PI4K2B | c.1302C>T p.D434= | Silent (SNP) | VAF 28/109 reads (26%) | catalogued as rs374166794; called by muse, mutect2, varscan2
- PITRM1 | c.468T>C p.F156= | Silent (SNP) | VAF 62/271 reads (23%) | called by muse, mutect2, varscan2
- PJA1 | c.429T>C p.T143= | Silent (SNP) | VAF 56/257 reads (22%) | catalogued as COSV64053593; called by muse, mutect2, varscan2
- PKLR | c.468C>T p.D156= | Silent (SNP) | VAF 34/799 reads (4%) | catalogued as rs1017711732; called by muse, mutect2
- PLD3 | c.693C>T p.G231= | Silent (SNP) | VAF 18/248 reads (7%) | catalogued as rs1301887491, COSV62926068; called by muse, mutect2
- PLEC | c.6855G>A p.R2285= (on ENST00000322810 / NM_201380.4; = p.R2175= on NM_000445.5) | Silent (SNP) | VAF 105/898 reads (12%) | catalogued as COSV59646810, COSV59671077; called by muse, mutect2, varscan2
- PLEK2 | c.450G>A p.E150= | Silent (SNP) | VAF 118/522 reads (23%) | catalogued as rs763006785; called by muse, mutect2, varscan2
- PLPPR3 | c.201C>T p.N67= | Silent (SNP) | VAF 169/651 reads (26%) | catalogued as rs370088177; called by muse, mutect2, varscan2
- PODXL | c.384T>C p.S128= | Silent (SNP) | VAF 138/517 reads (27%) | called by muse, mutect2, varscan2
- POM121L12 | c.852C>A p.A284= | Silent (SNP) | VAF 20/163 reads (12%) | catalogued as COSV101374923; called by muse, mutect2, varscan2
- PRC1 | c.1713C>T p.S571= | Silent (SNP) | VAF 11/104 reads (11%) | called by muse, mutect2, varscan2
- PRL | c.279C>T p.T93= | Silent (SNP) | VAF 37/560 reads (7%) | catalogued as COSV60593705; called by muse, mutect2
183 further variants in this file (0 protein-altering or splice-affecting, 45 silent, 138 other) are not listed here.
